Somatic mutation profile of tumor specimen MMRF_1796_1_BM_CD138pos (aliquot MMRF_1796_1_BM_CD138pos_T1_KBS5U_K11323) from MMRF case MMRF_1796, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 73.4 years (26,822 days).
Specimen MMRF_1796_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 631a1931-a532-4639-babd-940692f587e7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1796_1_PB_CD3pos (Blood Derived Normal), aliquot MMRF_1796_1_PB_CD3pos_C2_KBS5U_K11324; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7e9c84fb-3d66-4fb5-80f3-d46749f75b55

The open-access MAF lists 5,522 somatic variants for this specimen: 1,934 protein-altering or splice-affecting, 790 silent, 2,798 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,631, 3'UTR 1,422, Silent 790, Intron 762, 5'UTR 283, Nonsense Mutation 196, 3'Flank 121, 5'Flank 116, RNA 93, Splice Region 57, Splice Site 33, Frame Shift Del 7.

Variants (750 of 5,522; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABHD5 | c.16G>T p.E6* | Nonsense Mutation (SNP) | VAF 45/88 reads (51%) | catalogued as rs1553614642; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ATM | c.1321C>T p.Q441* | Nonsense Mutation (SNP) | VAF 61/138 reads (44%) | catalogued as rs1565382267; ClinVar: pathogenic; called by muse, mutect2, varscan2
- C3orf70 | c.17C>T p.S6L | Missense Mutation (SNP) | VAF 44/76 reads (58%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as rs757159118, COSV58586480, COSV58587413, COSV58588338; called by muse, mutect2, varscan2
- EDARADD | c.367G>A p.D123N (on ENST00000334232 / NM_145861.4; = p.D113N on NM_080738.4) | Missense Mutation (SNP) | VAF 55/116 reads (47%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.986); catalogued as rs879255629, CM1513606; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FOXL2 | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 79/172 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as CM082718, COSV57725966, COSV57728681; called by muse, mutect2, varscan2
- KCNQ1 | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs199472734, CM034234; ClinVar: not provided / uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- RPS6KA4 | c.707C>T p.S236L | Missense Mutation (SNP) | VAF 30/61 reads (49%) | hotspot (GDC flag); SIFT tolerated (0.18); PolyPhen probably damaging (0.997); catalogued as rs746466314, COSV53702062; called by muse, mutect2, varscan2
- A2M | c.3559C>T p.Q1187* | Nonsense Mutation (SNP) | VAF 21/43 reads (49%) | catalogued as COSV100588474; called by muse, mutect2, varscan2
- A2M | c.525C>G p.I175M | Missense Mutation (SNP) | VAF 61/113 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59383213; called by muse, mutect2, varscan2
- A4GNT | c.93C>G p.F31L | Missense Mutation (SNP) | VAF 79/174 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV99368037; called by muse, mutect2, varscan2
- ABCB6 | c.719G>A p.R240Q | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs535561406; called by muse, mutect2, varscan2
- ABL1 | c.238C>G p.L80V | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as COSV59331466; called by muse, mutect2, varscan2
- AC008397.2 | c.292C>G p.Q98E | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.101); catalogued as COSV53206284, COSV99441114, COSV99442346; called by muse, mutect2, varscan2
- AC068580.4 | c.964C>T p.Q322* | Nonsense Mutation (SNP) | VAF 39/78 reads (50%) | catalogued as COSV52588247; called by muse, mutect2, varscan2
- ACE | c.1252G>A p.E418K | Missense Mutation (SNP) | VAF 137/210 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52003371; called by muse, mutect2, varscan2
- ACER1 | c.22C>T p.Q8* | Nonsense Mutation (SNP) | VAF 46/181 reads (25%) | catalogued as COSV56836205; called by muse, mutect2
- ACRV1 | c.64C>T p.Q22* | Nonsense Mutation (SNP) | VAF 44/102 reads (43%) | catalogued as rs984112818; called by muse, mutect2, varscan2
- ACSM2B | c.1369C>T p.Q457* | Nonsense Mutation (SNP) | VAF 171/482 reads (35%) | catalogued as rs370210894; called by muse, mutect2, varscan2
- ACSM3 | c.1460G>A p.R487Q | Missense Mutation (SNP) | VAF 63/156 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); catalogued as rs1267372126, COSV55500169, COSV55502645; called by muse, mutect2, varscan2
- ADAD2 | c.608-1G>A p.X203_splice (on ENST00000315906 / NM_001145400.2; = p.X275_splice on NM_139174.4) | Splice Site (SNP) | VAF 96/288 reads (33%) | catalogued as COSV99235681; called by muse, mutect2, varscan2
- ADAMTS1 | c.1426G>A p.D476N | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.023); catalogued as rs765139475, COSV99536100; called by muse, mutect2, varscan2
- ADAMTS19 | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 9/198 reads (5%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as COSV99179023; called by muse, mutect2
- ADAMTS7 | c.1126G>C p.E376Q | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66309198; called by muse, mutect2, varscan2
- ADAMTSL1 | c.1669C>T p.Q557* | Nonsense Mutation (SNP) | VAF 30/60 reads (50%) | catalogued as COSV99444923; called by muse, mutect2, varscan2
- ADCY3 | c.1645G>A p.E549K | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (0.47); PolyPhen benign (0.015); catalogued as rs549867892; called by muse, varscan2
- ADGRV1 | c.11494G>A p.E3832K | Missense Mutation (SNP) | VAF 65/164 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.258); catalogued as COSV67989802; called by muse, mutect2, varscan2
- AFF2 | c.1540C>T p.R514C | Missense Mutation (SNP) | VAF 113/194 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs782804418; called by muse, mutect2, varscan2
- AFF3 | c.2392G>A p.E798K | Missense Mutation (SNP) | VAF 43/105 reads (41%) | SIFT tolerated (0.76); PolyPhen benign (0.197); catalogued as COSV57880636; called by muse, mutect2, varscan2
- AGRN | c.1810G>A p.D604N | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT tolerated (0.27); PolyPhen benign (0.014); catalogued as rs1328878396; called by muse, mutect2, varscan2
- AIRE | c.1103C>T p.P368L | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs552129156, COSV52393851, COSV52397149; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AJM1 | c.1442G>T p.R481L | Missense Mutation (SNP) | VAF 12/17 reads (71%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.693); catalogued as COSV56032526; called by muse, varscan2
- AJM1 | c.1456G>A p.E486K | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.247); catalogued as rs1201231888, COSV56035715; called by muse, varscan2
- AJUBA | c.307C>T p.Q103* | Nonsense Mutation (SNP) | VAF 38/79 reads (48%) | catalogued as COSV99401112; called by muse, mutect2, varscan2
- AKAP9 | c.10366G>A p.E3456K (on ENST00000359028; = p.E3432K on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 110/355 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1183330019; called by muse, mutect2, varscan2
- AKR1C3 | c.668G>A p.R223Q | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as rs782018434; called by muse, mutect2, varscan2
- AL592490.1 | c.1433C>T p.S478L | Missense Mutation (SNP) | VAF 85/177 reads (48%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV69426400; called by muse, mutect2, varscan2
- ALDH18A1 | c.1171C>T p.H391Y | Missense Mutation (SNP) | VAF 58/120 reads (48%) | SIFT tolerated (0.27); PolyPhen benign (0.16); catalogued as rs759279790; called by muse, mutect2, varscan2
- ALK | c.2404G>C p.E802Q | Missense Mutation (SNP) | VAF 47/101 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV66584565; called by muse, mutect2, varscan2
- ALMS1 | c.7352C>T p.S2451L | Missense Mutation (SNP) | VAF 59/114 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.526); catalogued as COSV52502907; called by muse, mutect2, varscan2
- ALPI | c.1360G>A p.E454K | Missense Mutation (SNP) | VAF 59/129 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.553); catalogued as COSV55014023; called by muse, mutect2, varscan2
- AMER1 | c.3256C>T p.Q1086* | Nonsense Mutation (SNP) | VAF 32/74 reads (43%) | catalogued as rs1296222452; called by muse, mutect2, varscan2
- AMER3 | c.2075C>T p.P692L | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs141716978, COSV58465062; called by muse, mutect2, varscan2
- ANK1 | c.1308A>G p.K436= | Splice Region (SNP) | VAF 27/58 reads (47%) | catalogued as rs1416109187; called by muse, mutect2, varscan2
- ANKLE2 | c.1421-3C>T | Splice Region (SNP) | VAF 15/28 reads (54%) | catalogued as rs369863535; called by muse, mutect2, varscan2
- ANKRD11 | c.4783G>A p.E1595K | Missense Mutation (SNP) | VAF 103/284 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV56355921; called by muse, mutect2, varscan2
- ANKRD30A | c.2005G>A p.E669K (on ENST00000611781; = p.E613K on NM_052997.2) | Missense Mutation (SNP) | VAF 84/145 reads (58%) | SIFT tolerated (0.59); PolyPhen benign (0.039); catalogued as rs150774137, COSV64623987; called by muse, mutect2, varscan2
- ANO1 | c.1579-1G>A p.X527_splice | Splice Site (SNP) | VAF 18/46 reads (39%) | catalogued as COSV60282799; called by muse, mutect2
- AP4B1 | c.1384G>A p.E462K | Missense Mutation (SNP) | VAF 87/183 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.243); catalogued as COSV56725439; called by muse, mutect2, varscan2
- ARFGAP2 | c.1364C>T p.S455L | Missense Mutation (SNP) | VAF 43/88 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.113); catalogued as rs368540395; called by muse, mutect2, varscan2
- ARHGAP31 | c.3404C>A p.S1135Y | Missense Mutation (SNP) | VAF 68/129 reads (53%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV51797326; called by muse, mutect2, varscan2
- ARHGAP4 | c.931G>A p.A311T | Missense Mutation (SNP) | VAF 66/132 reads (50%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs1557104652; called by muse, mutect2, varscan2
- ARHGAP9 | c.386C>G p.S129W | Missense Mutation (SNP) | VAF 53/90 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.524); catalogued as COSV62724553; called by muse, mutect2, varscan2
- ARHGEF12 | c.1350G>C p.K450N | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.984); catalogued as COSV63103617; called by muse, mutect2
- ARHGEF19 | c.987del p.P330Rfs*41 | Frame Shift Del (DEL) | VAF 15/54 reads (28%) | catalogued as rs1436223505; called by pindel, varscan2
- ARID2 | c.419-1G>A p.X140_splice | Splice Site (SNP) | VAF 53/116 reads (46%) | catalogued as COSV57596098; called by muse, mutect2, varscan2
- ARID4A | c.2470G>A p.E824K | Missense Mutation (SNP) | VAF 43/101 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.081); catalogued as rs1289100353; called by muse, mutect2, varscan2
- ARID4A | c.3064G>T p.E1022* | Nonsense Mutation (SNP) | VAF 113/237 reads (48%) | catalogued as COSV99049420; called by muse, mutect2, varscan2
- ARMC3 | c.115G>C p.E39Q | Missense Mutation (SNP) | VAF 50/99 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV53065506; called by muse, mutect2, varscan2
- ARMC4 | c.1318C>T p.R440C | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs376424270; ClinVar: uncertain significance; called by muse, mutect2
- ARSH | c.481C>T p.R161C | Missense Mutation (SNP) | VAF 47/97 reads (48%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.847); catalogued as rs755846145; called by muse, mutect2, varscan2
- ASCL2 | c.137G>A p.G46E | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.154); catalogued as rs771052351; called by mutect2, varscan2
- ASTL | c.910C>T p.P304S | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.007); catalogued as COSV60903705; called by muse, mutect2, varscan2
- ATE1 | c.703C>G p.Q235E | Missense Mutation (SNP) | VAF 108/221 reads (49%) | SIFT tolerated (0.29); PolyPhen benign (0.101); catalogued as COSV56436170; called by muse, mutect2, varscan2
- ATG2A | c.4376C>T p.S1459F | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as COSV65968654; called by muse, mutect2, varscan2
- ATIC | c.556G>A p.D186N | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV104377572; called by muse, mutect2, varscan2
- ATM | c.8081G>A p.G2694E | Missense Mutation (SNP) | VAF 60/126 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53723985; called by muse, mutect2, varscan2
- ATP13A4 | c.1177C>T p.Q393* | Nonsense Mutation (SNP) | VAF 38/64 reads (59%) | catalogued as COSV55069851, COSV55072452; called by muse, mutect2, varscan2
- ATP13A5 | c.3206G>A p.R1069Q | Missense Mutation (SNP) | VAF 40/80 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764104661, COSV60867915; called by muse, mutect2, varscan2
- ATP1A1 | c.1218G>C p.Q406H | Missense Mutation (SNP) | VAF 6/127 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.166); catalogued as rs1296073565; called by muse, mutect2
- ATP1A1 | c.1534G>A p.E512K | Missense Mutation (SNP) | VAF 43/86 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55192887; called by muse, mutect2, varscan2
- ATP2B4 | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0.027); catalogued as COSV58176602; called by muse, mutect2, varscan2
- ATRX | c.5140G>A p.D1714N | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100969947; called by muse, mutect2, varscan2
- ATXN7L2 | c.1943G>A p.R648Q | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs529417006; called by muse, mutect2, varscan2
- AUTS2 | c.149C>T p.S50L | Missense Mutation (SNP) | VAF 56/82 reads (68%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs775225727, COSV100719921; called by muse, mutect2, varscan2
- B3GALT4 | c.899G>A p.R300Q | Missense Mutation (SNP) | VAF 42/75 reads (56%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.772); catalogued as COSV101005541; called by muse, mutect2, varscan2
- B3GNT3 | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 56/305 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.081); catalogued as rs777983261; called by muse, mutect2, varscan2
- B4GALT5 | c.329C>T p.A110V | Missense Mutation (SNP) | VAF 16/209 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as COSV100866994; called by muse, mutect2
- BACE2 | c.172G>A p.D58N | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.5); PolyPhen benign (0.006); catalogued as rs1377506643, COSV57737272; called by muse, mutect2
- BBS4 | c.1456G>A p.G486R | Missense Mutation (SNP) | VAF 150/281 reads (53%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.08); catalogued as rs141373654; called by muse, mutect2, varscan2
- BBS9 | c.2501C>T p.P834L (on ENST00000242067 / NM_001348036.1; = p.P794L on NM_014451.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/99 reads (51%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.576); catalogued as COSV99625411, COSV99627349; called by muse, mutect2, varscan2
- BCAR1 | c.2152G>A p.D718N | Missense Mutation (SNP) | VAF 41/132 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs995979152, COSV99365898; called by muse, mutect2, varscan2
- BEND2 | c.1676G>A p.G559E | Missense Mutation (SNP) | VAF 53/117 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101191895; called by muse, mutect2, varscan2
- BEND2 | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 65/130 reads (50%) | SIFT tolerated (0.33); PolyPhen benign (0.014); catalogued as COSV66216803; called by muse, mutect2, varscan2
- BICC1 | c.2036C>T p.S679L | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.141); catalogued as rs1054902785; called by muse, mutect2, varscan2
- BICDL1 | c.1214C>T p.S405L | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.129); catalogued as rs374769468; called by muse, mutect2, varscan2
- BIN1 | c.550C>T p.Q184* | Nonsense Mutation (SNP) | VAF 59/119 reads (50%) | catalogued as COSV99387241; called by muse, mutect2, varscan2
- BPNT1 | c.541C>T p.Q181* | Nonsense Mutation (SNP) | VAF 32/74 reads (43%) | catalogued as COSV59040313; called by muse, mutect2, varscan2
- BRAT1 | c.1465G>A p.D489N | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs1420913778; called by muse, mutect2, varscan2
- BRIP1 | c.2911C>G p.P971A | Missense Mutation (SNP) | VAF 10/131 reads (8%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.254); catalogued as COSV52008670; called by muse, mutect2
- BRPF1 | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 62/142 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.7); catalogued as rs762698085, COSV57403655; called by muse, mutect2, varscan2
- BRWD1 | c.815C>G p.S272* | Nonsense Mutation (SNP) | VAF 91/199 reads (46%) | catalogued as COSV58122777; called by muse, mutect2, varscan2
- BRWD3 | c.3719G>C p.R1240P | Missense Mutation (SNP) | VAF 52/108 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV64752276, COSV64753268; called by muse, mutect2, varscan2
- BSN | c.11288C>T p.S3763L | Missense Mutation (SNP) | VAF 137/291 reads (47%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as rs771828722; called by muse, mutect2, varscan2
- BTBD11 | c.1783G>A p.D595N (on ENST00000280758 / NM_001018072.2; = p.D132N on NM_001017523.2) | Missense Mutation (SNP) | VAF 61/111 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.733); catalogued as rs142214499, COSV55019446; called by muse, mutect2, varscan2
- BTF3 | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as COSV60063828; called by muse, varscan2
- C12orf73 | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 138/248 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.359); catalogued as COSV65254749; called by muse, mutect2, varscan2
- C14orf39 | c.98G>A p.R33K | Missense Mutation (SNP) | VAF 60/120 reads (50%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.543); catalogued as COSV58781162; called by muse, mutect2, varscan2
- C17orf80 | c.90G>A p.M30I | Missense Mutation (SNP) | VAF 335/501 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV52147912; called by muse, mutect2, varscan2
- C1QTNF2 | c.960C>G p.I320M (on ENST00000393975; = p.I275M on NM_031908.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as rs1407939861; called by muse, mutect2, varscan2
- C1orf162 | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 164/407 reads (40%) | SIFT tolerated (0.76); PolyPhen benign (0.007); catalogued as COSV100636197; called by muse, mutect2, varscan2
- C20orf173 | c.64C>T p.H22Y | Missense Mutation (SNP) | VAF 80/153 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0.094); catalogued as rs1280578755, COSV55785879; called by muse, mutect2, varscan2
- C2CD3 | c.3372G>C p.Q1124H | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as COSV58089659; called by muse, mutect2, varscan2
- C2orf42 | c.718G>A p.E240K | Missense Mutation (SNP) | VAF 71/135 reads (53%) | SIFT tolerated (0.54); PolyPhen benign (0.277); catalogued as rs775103656; called by muse, mutect2, varscan2
- C2orf74 | c.550C>T p.R184* | Nonsense Mutation (SNP) | VAF 44/90 reads (49%) | catalogued as rs562908846, COSV67041817; called by muse, mutect2, varscan2
- C3orf70 | c.211C>T p.Q71* | Nonsense Mutation (SNP) | VAF 6/110 reads (5%) | catalogued as rs1434190286; called by muse, mutect2
- C4orf54 | c.2374G>A p.E792K | Missense Mutation (SNP) | VAF 92/181 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.115); catalogued as rs1249418139, COSV101552112; called by muse, mutect2, varscan2
- C8B | c.110C>T p.S37F | Missense Mutation (SNP) | VAF 85/165 reads (52%) | SIFT tolerated (0.73); PolyPhen benign (0.005); catalogued as rs761533195, COSV64777481; called by muse, mutect2, varscan2
- C8orf76 | c.851C>T p.S284L | Missense Mutation (SNP) | VAF 101/207 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs374975138, COSV99414859; called by muse, mutect2, varscan2
- CACTIN | c.200C>T p.S67L | Missense Mutation (SNP) | VAF 35/164 reads (21%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.007); catalogued as rs753340469; called by muse, mutect2, varscan2
- CACUL1 | c.267G>A p.M89I | Missense Mutation (SNP) | VAF 76/165 reads (46%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as rs1407479226; called by muse, mutect2, varscan2
- CACYBP | c.530+3G>A | Splice Region (SNP) | VAF 15/47 reads (32%) | catalogued as rs1270004661; called by muse, mutect2, varscan2
- CAMKK2 | c.46C>T p.P16S | Missense Mutation (SNP) | VAF 46/79 reads (58%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.073); catalogued as rs757852554; called by muse, mutect2, varscan2
- CAMSAP2 | c.3233C>G p.S1078* (on ENST00000236925 / NM_001297707.2; = p.S1067* on NM_203459.3) | Nonsense Mutation (SNP) | VAF 139/278 reads (50%) | catalogued as COSV52668120; called by muse, mutect2, varscan2
- CAPN3 | c.131C>T p.S44L | Missense Mutation (SNP) | VAF 55/103 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as rs370542189; called by muse, mutect2, varscan2
- CARMIL2 | c.437C>T p.S146L | Missense Mutation (SNP) | VAF 82/202 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs770638604; called by muse, mutect2, varscan2
- CASZ1 | c.2492C>T p.S831L | Missense Mutation (SNP) | VAF 46/81 reads (57%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.003); catalogued as COSV100681897, COSV59740993; called by muse, mutect2, varscan2
- CBX7 | c.533C>T p.P178L | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0.012); catalogued as rs200999757; called by muse, mutect2, varscan2
- CC2D1A | c.2053G>C p.D685H | Missense Mutation (SNP) | VAF 91/418 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58786676; called by muse, mutect2, varscan2
- CC2D1B | c.310G>C p.E104Q | Missense Mutation (SNP) | VAF 50/98 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.047); catalogued as rs1414554188; called by muse, varscan2
- CCDC113 | c.856G>C p.E286Q | Missense Mutation (SNP) | VAF 54/169 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.077); catalogued as COSV54685231; called by muse, mutect2, varscan2
- CCDC175 | c.463G>A p.D155N | Missense Mutation (SNP) | VAF 34/113 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.359); catalogued as COSV55787861; called by muse, mutect2, varscan2
- CCDC85C | c.333C>G p.H111Q | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as COSV66549704; called by muse, mutect2, varscan2
- CCDC93 | c.902C>T p.S301L | Missense Mutation (SNP) | VAF 41/74 reads (55%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV100098792; called by muse, varscan2
- CCHCR1 | c.2200G>A p.V734M | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.27); PolyPhen benign (0.135); catalogued as rs778324681, COSV52535551; called by muse, mutect2, varscan2
- CCKBR | c.136G>A p.G46R | Missense Mutation (SNP) | VAF 39/80 reads (49%) | SIFT tolerated (0.24); PolyPhen benign (0.376); catalogued as rs967491641, COSV58106176; called by muse, mutect2, varscan2
- CCNA2 | c.37G>A p.E13K | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.043); catalogued as COSV52655025, COSV99144834; called by muse, mutect2, varscan2
- CCNT1 | c.334C>T p.L112F | Missense Mutation (SNP) | VAF 10/200 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as COSV56064306; called by muse, mutect2
- CCP110 | c.1237C>G p.Q413E | Missense Mutation (SNP) | VAF 71/132 reads (54%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV66817108, COSV66818279; called by muse, mutect2, varscan2
- CD8B | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 70/165 reads (42%) | SIFT tolerated (0.25); PolyPhen benign (0.034); catalogued as rs749133219; called by muse, varscan2
- CDAN1 | c.2851G>C p.E951Q | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV62331396; called by muse, mutect2, varscan2
- CDC123 | c.412G>A p.D138N | Missense Mutation (SNP) | VAF 78/166 reads (47%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.96); catalogued as rs1319396144; called by muse, mutect2, varscan2
- CDC40 | c.568G>T p.D190Y | Missense Mutation (SNP) | VAF 71/151 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV100309618; called by muse, mutect2, varscan2
- CDC42BPA | c.685G>A p.D229N | Missense Mutation (SNP) | VAF 42/90 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.886); catalogued as rs558912714; called by muse, mutect2, varscan2
- CDCA2 | c.1649G>A p.R550K | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.26); PolyPhen benign (0.019); catalogued as rs370124521; called by muse, mutect2, varscan2
- CDH1 | c.1009-6C>T | Splice Region (SNP) | VAF 19/61 reads (31%) | catalogued as rs771652165; ClinVar: likely benign; called by muse, mutect2, varscan2
- CDH15 | c.916G>A p.D306N | Missense Mutation (SNP) | VAF 61/179 reads (34%) | SIFT tolerated (0.53); PolyPhen benign (0.018); catalogued as rs575142201, COSV57022439; called by muse, mutect2, varscan2
- CDK19 | c.15C>G p.F5L | Missense Mutation (SNP) | VAF 117/265 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV60447395, COSV60451659; called by muse, mutect2, varscan2
- CDKN1A | c.293C>A p.S98* | Nonsense Mutation (SNP) | VAF 37/88 reads (42%) | catalogued as COSV55188588, COSV55190422; called by muse, mutect2, varscan2
- CDKN1C | c.257C>T p.S86L | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.448); catalogued as rs897964106; called by muse, mutect2, varscan2
- CEACAM5 | c.1012G>A p.E338K | Missense Mutation (SNP) | VAF 84/174 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55751872; called by muse, mutect2, varscan2
- CELSR2 | c.8143+6G>C | Splice Region (SNP) | VAF 46/124 reads (37%) | catalogued as rs1253831866; called by muse, mutect2, varscan2
- CELSR3 | c.2210C>T p.S737F | Missense Mutation (SNP) | VAF 66/135 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1406061851; called by muse, mutect2, varscan2
- CENPB | c.1427G>A p.W476* | Nonsense Mutation (SNP) | VAF 90/94 reads (96%) | catalogued as COSV100713176; called by muse, mutect2, varscan2
- CENPJ | c.2901G>A p.M967I | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs757953924; called by muse, mutect2, varscan2
- CENPN | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 46/138 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as COSV100001129; called by muse, mutect2, varscan2
- CERS2 | c.915C>G p.F305L | Missense Mutation (SNP) | VAF 41/87 reads (47%) | SIFT tolerated (0.23); PolyPhen benign (0.208); catalogued as COSV54991048; called by muse, mutect2, varscan2
- CFAP299 | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 60/123 reads (49%) | SIFT tolerated (0.15); PolyPhen benign (0.049); catalogued as COSV63884038; called by muse, mutect2, varscan2
- CFAP65 | c.3759G>C p.Q1253H | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV58562990; called by muse, mutect2, varscan2
- CFAP97 | c.212del p.R71Kfs*3 | Frame Shift Del (DEL) | VAF 68/173 reads (39%) | catalogued as COSV57111180; called by mutect2, pindel, varscan2
- CHD3 | c.4570G>A p.D1524N | Missense Mutation (SNP) | VAF 112/340 reads (33%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.972); catalogued as rs376704763; called by muse, mutect2, varscan2
- CHM | c.1448G>A p.G483E | Missense Mutation (SNP) | VAF 101/221 reads (46%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.866); catalogued as COSV100753149; called by muse, mutect2, varscan2
- CHN1 | c.641G>C p.R214T | Missense Mutation (SNP) | VAF 142/328 reads (43%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.926); catalogued as COSV55033816; called by muse, mutect2, varscan2
- CHN1 | c.535G>A p.V179M | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as rs368672805; called by muse, mutect2, varscan2
- CHSY3 | c.1072G>A p.V358I | Missense Mutation (SNP) | VAF 49/100 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.066); catalogued as COSV59289069; called by muse, mutect2, varscan2
- CIAO3 | c.470C>T p.S157L | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.371); catalogued as rs1188955841, COSV52403941; called by muse, mutect2, varscan2
- CILP2 | c.975C>T p.S325= | Splice Region (SNP) | VAF 53/229 reads (23%) | catalogued as rs748708643; called by muse, mutect2, varscan2
- CLCF1 | c.634C>T p.P212S | Missense Mutation (SNP) | VAF 58/117 reads (50%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs557074766; called by muse, mutect2, varscan2
- CLDN18 | c.748G>A p.E250K | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.017); catalogued as rs1053286810, COSV51736004; called by muse, mutect2, varscan2
- CMPK2 | c.1007C>T p.T336M | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753647983; called by muse, mutect2, varscan2
- CMTM7 | c.435C>G p.I145M | Missense Mutation (SNP) | VAF 38/73 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.695); catalogued as COSV58552264; called by muse, mutect2, varscan2
- CMYA5 | c.11840G>A p.W3947* | Nonsense Mutation (SNP) | VAF 24/56 reads (43%) | catalogued as rs752948838; called by muse, mutect2, varscan2
- CNTROB | c.2333C>T p.S778F | Missense Mutation (SNP) | VAF 139/216 reads (64%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.748); catalogued as rs1240368190; called by muse, mutect2, varscan2
- COG1 | c.169C>T p.R57C | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781738369, COSV100245428; called by muse, mutect2, varscan2
- COG7 | c.965C>T p.A322V | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as rs748422293; called by muse, mutect2, varscan2
- COL18A1 | c.2704C>G p.R902G (on ENST00000359759 / NM_130444.3; = p.R667G on NM_030582.4) | Missense Mutation (SNP) | VAF 53/105 reads (50%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.989); catalogued as COSV100700646; called by muse, mutect2, varscan2
- COL27A1 | c.496C>T p.R166C | Missense Mutation (SNP) | VAF 57/93 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as rs748820491; called by muse, mutect2, varscan2
- COL27A1 | c.3887C>T p.P1296L | Missense Mutation (SNP) | VAF 42/87 reads (48%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.999); catalogued as rs772475329, COSV100621235; called by muse, mutect2, varscan2
- COL6A6 | c.2621C>T p.S874L | Missense Mutation (SNP) | VAF 78/140 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.437); catalogued as rs200368776; called by muse, mutect2, varscan2
- COL7A1 | c.6770G>A p.G2257E | Missense Mutation (SNP) | VAF 136/315 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM071639; called by muse, mutect2, varscan2
- COL9A1 | c.490C>T p.L164F | Missense Mutation (SNP) | VAF 97/207 reads (47%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.511); catalogued as rs749263101; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COMT | c.365C>T p.S122L | Missense Mutation (SNP) | VAF 40/77 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52889652; called by muse, mutect2, varscan2
- COMTD1 | c.101G>A p.R34Q | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0.13); catalogued as rs748093164; called by muse, mutect2, varscan2
- COQ8B | c.1447G>A p.E483K | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.79); catalogued as rs398122980, CM1311973; called by muse, mutect2, varscan2
- COQ9 | c.631C>T p.H211Y | Missense Mutation (SNP) | VAF 61/194 reads (31%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.566); catalogued as COSV52646258; called by muse, mutect2, varscan2
- CORO7 | c.2749G>A p.E917K | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV52029476; called by muse, mutect2, varscan2
- CPEB4 | c.1369C>T p.H457Y | Missense Mutation (SNP) | VAF 66/145 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.053); catalogued as COSV54171777; called by muse, mutect2, varscan2
- CPLX4 | c.365C>G p.S122C | Missense Mutation (SNP) | VAF 22/194 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100231516, COSV55314238; called by muse, mutect2
- CPN2 | c.832C>T p.R278W | Missense Mutation (SNP) | VAF 80/149 reads (54%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.761); catalogued as rs770853665, COSV60469923; called by muse, mutect2
- CPSF1 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.21); catalogued as COSV62942361; called by muse, mutect2, varscan2
- CRTC1 | c.1279G>C p.E427Q | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.024); catalogued as COSV58718054; called by muse, mutect2, varscan2
- CRYAB | c.148C>T p.R50W | Missense Mutation (SNP) | VAF 44/96 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1555165555, COSV99909855; called by muse, mutect2, varscan2
- CSMD1 | c.8446G>A p.E2816K (on ENST00000520002; = p.E2815K on NM_033225.6) | Missense Mutation (SNP) | VAF 111/214 reads (52%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.987); catalogued as COSV100153951; called by muse, mutect2, varscan2
- CSMD3 | c.7228G>A p.D2410N (on ENST00000297405 / NM_001363185.1; = p.D2306N on NM_052900.3) | Missense Mutation (SNP) | VAF 81/202 reads (40%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.999); catalogued as COSV52159870; called by muse, mutect2, varscan2
- CSMD3 | c.4720C>T p.R1574W (on ENST00000297405 / NM_001363185.1; = p.R1470W on NM_052900.3) | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs776470969, COSV52272801, COSV52274444; called by muse, mutect2, varscan2
- CSMD3 | c.4568C>T p.S1523F (on ENST00000297405 / NM_001363185.1; = p.S1419F on NM_052900.3) | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.943); catalogued as COSV52103216, COSV52110256; called by muse, mutect2, varscan2
- CSRNP3 | c.1036G>A p.E346K | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.702); catalogued as COSV100086077; called by muse, mutect2, varscan2
- CTBP1 | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1247105966; called by muse, mutect2, varscan2
- CTC1 | c.955G>A p.E319K | Missense Mutation (SNP) | VAF 56/198 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV100236155; called by muse, mutect2
- CTCF | c.1432G>T p.E478* | Nonsense Mutation (SNP) | VAF 24/91 reads (26%) | catalogued as COSV50463975, COSV99866622; called by muse, mutect2, varscan2
- CTTNBP2 | c.3573G>T p.K1191N | Missense Mutation (SNP) | VAF 44/72 reads (61%) | SIFT tolerated (0.21); PolyPhen benign (0.062); catalogued as COSV50393636; called by muse, mutect2, varscan2
- CUBN | c.7099C>T p.L2367F | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.376); catalogued as COSV64712427; called by muse, mutect2, varscan2
- CUX1 | c.3329G>A p.G1110E | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs782788239; called by muse, mutect2, varscan2
- CUX2 | c.2485G>A p.E829K | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT tolerated (0.38); PolyPhen benign (0.036); catalogued as rs765779977, COSV55635837; called by muse, mutect2, varscan2
- CYLC2 | c.422C>T p.S141L | Missense Mutation (SNP) | VAF 50/93 reads (54%) | SIFT tolerated (0.3); PolyPhen benign (0.009); catalogued as COSV66337654; called by muse, mutect2, varscan2
- CYP17A1 | c.412G>A p.G138S | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as rs1485258085; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CYP39A1 | c.1121G>A p.R374K | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51493534; called by muse, mutect2, varscan2
- CYP3A5 | c.716C>T p.S239F | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.078); catalogued as COSV56122275; called by muse, mutect2, varscan2
- CYTH1 | c.946G>T p.E316* | Nonsense Mutation (SNP) | VAF 79/123 reads (64%) | catalogued as COSV63119844; called by muse, mutect2, varscan2
- DACH2 | c.166G>A p.G56R | Missense Mutation (SNP) | VAF 54/114 reads (47%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as COSV64168914; called by muse, mutect2, varscan2
- DARS2 | c.1027G>A p.D343N | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.962); catalogued as COSV53409146; called by muse, mutect2, varscan2
- DAZAP1 | c.62C>T p.T21M | Missense Mutation (SNP) | VAF 31/172 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761599602, COSV51836589; called by muse, mutect2, varscan2
- DCDC1 | c.1703C>T p.S568L | Missense Mutation (SNP) | VAF 47/73 reads (64%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs776704634, COSV60835487; called by muse, mutect2, varscan2
- DCDC2B | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.934); catalogued as rs1398098856; called by muse, varscan2
- DDN | c.454C>T p.R152W | Missense Mutation (SNP) | VAF 47/83 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.027); catalogued as rs1275892641; called by muse, mutect2, varscan2
- DDX19B | c.148G>T p.E50* | Nonsense Mutation (SNP) | VAF 91/152 reads (60%) | catalogued as rs1203650444; called by muse, mutect2, varscan2
- DDX54 | c.2307G>C p.Q769H | Missense Mutation (SNP) | VAF 40/83 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); catalogued as rs1271090120; called by muse, mutect2, varscan2
- DEF6 | c.1351G>A p.D451N | Missense Mutation (SNP) | VAF 61/124 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs201800476; called by muse, mutect2, varscan2
- DENND2C | c.1825G>A p.E609K (on ENST00000393274 / NM_001256404.2; = p.E552K on NM_198459.4) | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67920984; called by muse, mutect2, varscan2
- DEPDC5 | c.896C>G p.S299C | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV56694502; called by muse, mutect2, varscan2
- DHFR | c.197G>A p.R66Q | Missense Mutation (SNP) | VAF 100/199 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs752733264; called by muse, mutect2, varscan2
- DICER1 | c.1468C>T p.R490C | Missense Mutation (SNP) | VAF 55/145 reads (38%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.91); catalogued as rs777894117, COSV58627328; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DICER1 | c.776C>T p.P259L | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.019); catalogued as rs566464225; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DISP2 | c.3989G>A p.R1330Q | Missense Mutation (SNP) | VAF 61/132 reads (46%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.933); catalogued as rs756030312, COSV51126893; called by muse, varscan2
- DISP3 | c.1078G>A p.D360N | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.997); catalogued as COSV99609277; called by muse, mutect2, varscan2
- DLG3 | c.1153C>A p.R385S (on ENST00000374360 / NM_021120.4; = p.R48S on NM_020730.3) | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as COSV52084719; called by muse, mutect2, varscan2
- DLG5 | c.2597C>T p.S866F | Missense Mutation (SNP) | VAF 62/137 reads (45%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs1268208200, COSV64947968; called by muse, mutect2, varscan2
- DLGAP2 | c.1299G>A p.M433I | Missense Mutation (SNP) | VAF 34/62 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.052); catalogued as COSV101421994; called by muse, mutect2, varscan2
- DLGAP3 | c.1158G>T p.E386D | Missense Mutation (SNP) | VAF 75/158 reads (47%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.874); catalogued as COSV99332020; called by muse, mutect2, varscan2
- DNAAF1 | c.1807C>G p.L603V | Missense Mutation (SNP) | VAF 85/224 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.275); catalogued as rs774702739; called by muse, mutect2, varscan2
- DNAH12 | c.7800G>C p.Q2600H (on ENST00000351747; = p.Q3468H on NM_001366028.2) | Missense Mutation (SNP) | VAF 94/205 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61064530; called by muse, mutect2, varscan2
- DNAH2 | c.7271C>G p.S2424C | Missense Mutation (SNP) | VAF 53/175 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV101209491; called by muse, mutect2, varscan2
- DNAH5 | c.12403C>A p.H4135N | Missense Mutation (SNP) | VAF 107/184 reads (58%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.493); catalogued as COSV54255031; called by muse, mutect2, varscan2
- DNAH5 | c.11616C>G p.I3872M | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); catalogued as rs773699669, COSV54204663; called by muse, mutect2, varscan2
- DNAH8 | c.12568C>T p.Q4190* | Nonsense Mutation (SNP) | VAF 38/73 reads (52%) | catalogued as COSV100542697; called by muse, mutect2, varscan2
- DOCK11 | c.3917C>T p.S1306L | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT tolerated (0.1); PolyPhen benign (0.313); catalogued as rs1252227645, COSV52234859; called by muse, mutect2, varscan2
- DOCK3 | c.6080G>A p.R2027Q | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.028); catalogued as rs782081576, COSV56551288; called by muse, mutect2, varscan2
- DOCK9 | c.3046G>C p.E1016Q (on ENST00000376460 / NM_001366676.2; = p.E1017Q on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 66/132 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.066); catalogued as COSV59624358; called by muse, mutect2, varscan2
- DOK1 | c.1337C>T p.S446L | Missense Mutation (SNP) | VAF 44/93 reads (47%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs1267080322; called by muse, mutect2, varscan2
- DPP7 | c.144C>A p.F48L | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs770784136; called by muse, mutect2
- DSCAML1 | c.2914G>A p.D972N (on ENST00000321322; = p.D912N on NM_020693.4) | Missense Mutation (SNP) | VAF 47/98 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.438); catalogued as rs779728724, COSV58405045; called by muse, mutect2, varscan2
- DTX3L | c.842C>T p.S281L | Missense Mutation (SNP) | VAF 98/203 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs1418103933; called by muse, mutect2, varscan2
- DVL1 | c.707C>G p.S236C | Missense Mutation (SNP) | VAF 74/132 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV66680918; called by muse, mutect2, varscan2
- EARS2 | c.113G>C p.R38P | Missense Mutation (SNP) | VAF 38/67 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54843036, COSV54843089; called by muse, mutect2, varscan2
- EEF1B2 | c.292G>A p.D98N | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.216); catalogued as COSV99261208; called by muse, mutect2, varscan2
- EFNA3 | c.610C>A p.Q204K | Missense Mutation (SNP) | VAF 121/257 reads (47%) | SIFT tolerated (0.4); PolyPhen benign (0.012); catalogued as COSV63625914; called by muse, mutect2, varscan2
- EHD2 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 134/281 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs1446462850, COSV99621560; called by muse, mutect2, varscan2
- EIF1 | c.126G>C p.K42N | Missense Mutation (SNP) | VAF 59/178 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as COSV60423002; called by muse, mutect2, varscan2
- EIF4ENIF1 | c.2830C>T p.R944C | Missense Mutation (SNP) | VAF 51/96 reads (53%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.899); catalogued as rs757609510, COSV57516988; called by muse, mutect2, varscan2
- EIF4G3 | c.22C>T p.R8C | Missense Mutation (SNP) | VAF 83/178 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.833); catalogued as COSV100796883, COSV100796984; called by muse, mutect2, varscan2
- ELMO3 | c.1921G>A p.E641K (on ENST00000652269; = p.E588K on NM_024712.5) | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as rs373878246; called by muse, mutect2, varscan2
- EME2 | c.118G>A p.D40N | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as rs1367365607; called by muse, mutect2, varscan2
- ENPEP | c.125C>T p.S42L | Missense Mutation (SNP) | VAF 62/121 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV54457824; called by muse, mutect2, varscan2
- ENPP6 | c.970G>A p.D324N | Missense Mutation (SNP) | VAF 76/182 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); catalogued as COSV57068414; called by muse, mutect2, varscan2
- ENTHD1 | c.1087G>A p.E363K | Missense Mutation (SNP) | VAF 70/155 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100289087; called by muse, mutect2, varscan2
- EPHA1 | c.2758G>A p.E920K | Missense Mutation (SNP) | VAF 67/197 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.066); catalogued as rs146963652; called by muse, mutect2, varscan2
- EPHA3 | c.892G>A p.E298K | Missense Mutation (SNP) | VAF 73/172 reads (42%) | SIFT tolerated (0.58); PolyPhen benign (0.089); catalogued as COSV60702588; called by muse, mutect2, varscan2
- EPHA6 | c.2755G>A p.D919N (on ENST00000389672 / NM_001080448.3; = p.D311N on NM_173655.4) | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs758493908, COSV67585469, COSV67590499; called by muse, mutect2, varscan2
- EPHX2 | c.1330G>A p.E444K | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.709); catalogued as COSV66846204; called by muse, mutect2, varscan2
- ERG28 | c.-31-1G>A | Splice Site (SNP) | VAF 105/228 reads (46%) | catalogued as rs1399258304, COSV99709707; called by muse, mutect2, varscan2
- ERICH3 | c.1564C>T p.Q522* | Nonsense Mutation (SNP) | VAF 70/150 reads (47%) | catalogued as COSV58615709; called by muse, mutect2, varscan2
- ERO1B | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs1259127404; called by muse, mutect2, varscan2
- ESYT1 | c.2077C>T p.R693W | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs764684970; called by muse, mutect2, varscan2
- EXPH5 | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 91/191 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.559); catalogued as rs879075071; called by muse, mutect2
- EZH2 | c.1570G>A p.D524N (on ENST00000460911 / NM_001203247.2; = p.D529N on NM_004456.5) | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.987); catalogued as COSV100235691; called by muse, mutect2, varscan2
- F7 | c.920G>A p.R307H | Missense Mutation (SNP) | VAF 54/120 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.088); catalogued as rs121964929, CM940391; called by muse, mutect2, varscan2
- FAM160A2 | c.934C>T p.Q312* | Nonsense Mutation (SNP) | VAF 30/69 reads (43%) | catalogued as COSV56409308; called by muse, mutect2, varscan2
- FAM189A2 | c.360C>A p.I120= | Splice Region (SNP) | VAF 74/181 reads (41%) | catalogued as COSV57385427; called by muse, mutect2, varscan2
- FAM83G | c.1369G>A p.A457T | Missense Mutation (SNP) | VAF 42/140 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as rs776432523, COSV58756642; called by muse, mutect2, varscan2
- FASLG | c.470C>T p.S157F | Missense Mutation (SNP) | VAF 45/113 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.687); catalogued as COSV60679894; called by muse, mutect2, varscan2
- FAT1 | c.8943G>C p.K2981N | Missense Mutation (SNP) | VAF 81/172 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.383); catalogued as COSV71673666; called by muse, mutect2, varscan2
- FAT3 | c.7510G>A p.E2504K | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as COSV53183030; called by muse, mutect2
- FBLN7 | c.104C>T p.S35L | Missense Mutation (SNP) | VAF 34/69 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.023); catalogued as rs756782622; called by muse, mutect2, varscan2
- FBLN7 | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 47/112 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs776911504, COSV55616657; called by muse, mutect2, varscan2
- FBN2 | c.4957G>A p.E1653K | Missense Mutation (SNP) | VAF 59/135 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1329599303, COSV99328856; called by muse, mutect2, varscan2
- FBN3 | c.8091G>A p.V2697= | Splice Region (SNP) | VAF 35/125 reads (28%) | catalogued as COSV99495219; called by muse, mutect2, varscan2
- FBXL16 | c.772G>A p.D258N | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV100179176; called by muse, mutect2, varscan2
- FBXL20 | c.1112C>T p.S371F | Missense Mutation (SNP) | VAF 45/74 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); catalogued as COSV52904530; called by muse, mutect2, varscan2
- FBXL8 | c.919G>C p.E307Q | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.879); catalogued as rs751771806, COSV50456818, COSV50457131; called by muse, mutect2, varscan2
- FBXO31 | c.296G>A p.R99H | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (1); PolyPhen possibly damaging (0.781); catalogued as rs1394951136, COSV61149929; called by muse, mutect2, varscan2
- FBXO40 | c.737C>T p.S246F | Missense Mutation (SNP) | VAF 87/192 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.179); catalogued as COSV99080496; called by muse, mutect2, varscan2
- FBXO45 | c.686G>A p.R229K | Missense Mutation (SNP) | VAF 36/70 reads (51%) | SIFT tolerated (0.52); PolyPhen benign (0.217); catalogued as COSV61146124; called by muse, mutect2
- FCGBP | c.6829G>A p.A2277T | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.609); catalogued as rs1029540901; called by muse, mutect2
- FCSK | c.2963C>T p.S988L | Missense Mutation (SNP) | VAF 27/36 reads (75%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs540730922, COSV55369993; called by muse, mutect2
- FERMT1 | c.1348G>A p.E450K | Missense Mutation (SNP) | VAF 65/136 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1478026917; called by muse, mutect2, varscan2
- FERMT2 | c.1670G>A p.R557K | Missense Mutation (SNP) | VAF 56/133 reads (42%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.657); catalogued as COSV100448853; called by muse, mutect2, varscan2
- FJX1 | c.571G>C p.E191Q | Missense Mutation (SNP) | VAF 42/70 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100502797, COSV58553013; called by muse, mutect2, varscan2
- FLG | c.8707G>C p.D2903H | Missense Mutation (SNP) | VAF 64/217 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.97); catalogued as COSV64236448; called by muse, mutect2, varscan2
- FLRT3 | c.1042C>A p.L348I | Missense Mutation (SNP) | VAF 57/114 reads (50%) | SIFT tolerated (0.2); PolyPhen benign (0.255); catalogued as COSV54037009; called by muse, mutect2, varscan2
- FLT1 | c.2957C>T p.S986F | Missense Mutation (SNP) | VAF 69/145 reads (48%) | SIFT tolerated (0.6); PolyPhen benign (0.011); catalogued as rs757344268; called by muse, mutect2, varscan2
- FNBP4 | c.1684G>A p.E562K | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV55446501; called by muse, mutect2, varscan2
- FOLH1 | c.503G>A p.G168E | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs267602926; called by muse, mutect2, varscan2
- FOXA2 | c.1151C>T p.S384L (on ENST00000377115 / NM_153675.3; = p.S390L on NM_021784.5) | Missense Mutation (SNP) | VAF 48/109 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1420632266, COSV65796035; called by muse, mutect2, varscan2
- FOXF1 | c.1022G>A p.R341Q | Missense Mutation (SNP) | VAF 95/304 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52288655; called by muse, mutect2, varscan2
- FOXL1 | c.913C>T p.R305C | Missense Mutation (SNP) | VAF 52/165 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs369054293; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.1865G>A p.R622Q | Missense Mutation (SNP) | VAF 71/145 reads (49%) | SIFT tolerated (0.33); PolyPhen benign (0.125); catalogued as rs202205355, COSV58545193; called by muse, mutect2, varscan2
- FRAS1 | c.6214G>A p.E2072K | Missense Mutation (SNP) | VAF 17/23 reads (74%) | SIFT tolerated (0.09); PolyPhen benign (0.367); catalogued as rs1390994485; called by muse, mutect2, varscan2
- FSBP | c.667G>A p.E223K | Missense Mutation (SNP) | VAF 180/364 reads (49%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs770900053; called by muse, mutect2, varscan2
- FSIP1 | c.53C>T p.S18L | Missense Mutation (SNP) | VAF 152/314 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63225344, COSV63225959; called by muse, mutect2, varscan2
- FUT4 | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.006); catalogued as rs373252364; called by muse, varscan2
- FZD1 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 87/254 reads (34%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.903); catalogued as COSV55313074; called by muse, mutect2, varscan2
- FZR1 | c.468G>C p.K156N | Missense Mutation (SNP) | VAF 92/379 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV100553495; called by muse, mutect2, varscan2
- GABRB2 | c.1447G>A p.D483N (on ENST00000274547; = p.D445N on NM_000813.3) | Missense Mutation (SNP) | VAF 78/159 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1409431535; called by muse, mutect2, varscan2
- GABRR3 | c.725C>T p.S242F | Missense Mutation (SNP) | VAF 74/133 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV72084341, COSV72084384; called by muse, mutect2, varscan2
- GCDH | c.244C>G p.R82G | Missense Mutation (SNP) | VAF 62/303 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.547); catalogued as COSV53434825; called by muse, mutect2, varscan2
- GCM1 | c.891G>T p.W297C | Missense Mutation (SNP) | VAF 85/173 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV52523181; called by muse, mutect2, varscan2
- GCN1 | c.7936G>A p.E2646K | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as rs1398500944; called by muse, mutect2, varscan2
- GEMIN2 | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 73/154 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as COSV99158005; called by muse, mutect2, varscan2
- GFPT1 | c.110C>G p.S37C | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100623039; called by muse, mutect2, varscan2
- GIMAP2 | c.248C>T p.S83F | Missense Mutation (SNP) | VAF 45/131 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV56235302, COSV56236650; called by muse, mutect2, varscan2
- GIPC1 | c.-30-1G>C | Splice Site (SNP) | VAF 28/104 reads (27%) | catalogued as rs750856821; called by muse, mutect2, varscan2
- GIT1 | c.696C>G p.F232L | Missense Mutation (SNP) | VAF 30/51 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.222); catalogued as COSV56613247; called by muse, mutect2, varscan2
- GIT2 | c.334C>A p.Q112K | Missense Mutation (SNP) | VAF 41/91 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.349); catalogued as COSV58079605; called by muse, mutect2, varscan2
- GJB6 | c.727G>A p.E243K | Missense Mutation (SNP) | VAF 106/200 reads (53%) | SIFT tolerated (0.26); PolyPhen benign (0.036); catalogued as COSV53832368; called by muse, mutect2, varscan2
- GK | c.1006C>T p.R336C (on ENST00000427190 / NM_001205019.2; = p.R330C on NM_000167.6) | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV66732482; called by muse, mutect2
- GLB1L3 | c.163C>T p.H55Y | Missense Mutation (SNP) | VAF 42/72 reads (58%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as rs1187951481; called by muse, mutect2, varscan2
- GLCCI1 | c.5C>T p.S2F | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.563); catalogued as rs1459889704; called by muse, mutect2, varscan2
- GLI1 | c.2312C>G p.S771* | Nonsense Mutation (SNP) | VAF 37/95 reads (39%) | catalogued as COSV57366208; called by muse, mutect2, varscan2
- GLRX3 | c.859G>T p.E287* | Nonsense Mutation (SNP) | VAF 21/48 reads (44%) | catalogued as COSV58692013; called by muse, mutect2, varscan2
- GNL3L | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 50/107 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.029); catalogued as rs960377711; called by muse, mutect2, varscan2
- GP2 | c.1268C>G p.S423* (on ENST00000381362 / NM_001007240.3; = p.S420* on NM_001502.4) | Nonsense Mutation (SNP) | VAF 51/89 reads (57%) | catalogued as COSV56896221; called by muse, mutect2, varscan2
- GPIHBP1 | c.46C>T p.R16W | Missense Mutation (SNP) | VAF 38/72 reads (53%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs779309481; called by muse, mutect2
- GPR142 | c.262G>C p.D88H | Missense Mutation (SNP) | VAF 77/109 reads (71%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.201); catalogued as rs1463141053; called by muse, mutect2, varscan2
- GPR143 | c.13C>T p.R5C | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs62635289, CM003022; ClinVar: not provided; called by muse, mutect2, varscan2
- GPR149 | c.229G>A p.D77N | Missense Mutation (SNP) | VAF 87/183 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1244639815; called by muse, mutect2, varscan2
- GPR25 | c.436G>T p.E146* | Nonsense Mutation (SNP) | VAF 10/21 reads (48%) | catalogued as rs201644801; called by muse, mutect2, varscan2
- GPR4 | c.553C>T p.R185W | Missense Mutation (SNP) | VAF 69/174 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59916140; called by muse, mutect2, varscan2
- GPRASP1 | c.2293G>A p.D765N | Missense Mutation (SNP) | VAF 48/90 reads (53%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as COSV99053760; called by muse, mutect2, varscan2
- GPS2 | c.165G>C p.E55D | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.971); catalogued as rs1442782338; called by muse, mutect2, varscan2
- GRAP2 | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 67/149 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV59994224; called by muse, mutect2, varscan2
- GRB10 | c.778-1G>C p.X260_splice | Splice Site (SNP) | VAF 44/98 reads (45%) | catalogued as COSV100240559; called by muse, varscan2
- GRIN2A | c.2011C>T p.Q671* | Nonsense Mutation (SNP) | VAF 26/54 reads (48%) | catalogued as rs1555491689, COSV100409689, COSV58052583; called by muse, mutect2, varscan2
- GRIN2B | c.3284C>T p.S1095L | Missense Mutation (SNP) | VAF 127/227 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.854); catalogued as COSV74205144; called by muse, mutect2, varscan2
- GRIN2C | c.1504C>T p.R502W | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs563450892, COSV53116640; called by muse, mutect2, varscan2
- GRIPAP1 | c.268C>T p.R90C | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1557067017; called by muse, mutect2, varscan2
- GRM2 | c.1504G>A p.E502K | Missense Mutation (SNP) | VAF 56/118 reads (47%) | SIFT tolerated (0.72); PolyPhen benign (0.102); catalogued as COSV56587129; called by muse, mutect2, varscan2
- GSTM3 | c.580-3C>T | Splice Region (SNP) | VAF 136/288 reads (47%) | catalogued as rs1440997960, COSV56663250; called by muse, mutect2, varscan2
- GSTO2 | c.104C>T p.S35F | Missense Mutation (SNP) | VAF 87/202 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.393); catalogued as rs879138026, COSV58538031; called by muse, mutect2, varscan2
- GTF3C1 | c.1771G>A p.E591K | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as COSV100648883; called by muse, mutect2, varscan2
- GYS1 | c.2074G>A p.E692K | Missense Mutation (SNP) | VAF 6/8 reads (75%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.039); catalogued as rs1008639380, COSV54402455; called by muse, mutect2, varscan2
- GYS2 | c.1480G>A p.E494K | Missense Mutation (SNP) | VAF 44/92 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.816); catalogued as rs866977819; called by muse, mutect2, varscan2
- H2AC15 | c.5C>A p.S2* | Nonsense Mutation (SNP) | VAF 17/92 reads (18%) | catalogued as rs188027160; called by muse, mutect2, varscan2
- HEATR6 | c.3430G>A p.A1144T | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as COSV51745263; called by muse, mutect2, varscan2
- HERC5 | c.3043G>A p.E1015K | Missense Mutation (SNP) | VAF 150/337 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.065); catalogued as rs751293985, COSV52043082; called by muse, varscan2
- HEXIM2 | c.751G>A p.E251K | Missense Mutation (SNP) | VAF 28/143 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.036); catalogued as rs1279380736; called by muse, mutect2, varscan2
- HHATL | c.1273C>A p.R425S | Missense Mutation (SNP) | VAF 62/126 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55136910; called by muse, mutect2, varscan2
- HLA-DOB | c.65C>T p.S22F | Missense Mutation (SNP) | VAF 88/186 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs555199989; called by muse, mutect2, varscan2
- HLA-F | c.357G>A p.M119I | Missense Mutation (SNP) | VAF 62/111 reads (56%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.021); catalogued as COSV99466307; called by muse, mutect2, varscan2
- HLF | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 102/155 reads (66%) | SIFT tolerated (0.06); PolyPhen benign (0.057); catalogued as COSV56832489; called by muse, mutect2, varscan2
- HMCN1 | c.10039G>A p.D3347N | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT tolerated (0.32); PolyPhen benign (0.111); catalogued as COSV54910043; called by muse, mutect2, varscan2
- HOXA2 | c.409G>A p.D137N | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.02); catalogued as COSV56067273; called by muse, mutect2
- HOXC11 | c.74G>A p.R25Q | Missense Mutation (SNP) | VAF 112/246 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs199765463, COSV54534143; called by muse, mutect2, varscan2
- HOXD9 | c.494G>A p.R165Q | Missense Mutation (SNP) | VAF 73/150 reads (49%) | SIFT tolerated (0.31); PolyPhen benign (0.019); catalogued as rs576187632; called by muse, mutect2, varscan2
- HS3ST4 | c.973G>A p.D325N | Missense Mutation (SNP) | VAF 66/139 reads (47%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.999); catalogued as rs780566032, COSV58826575; called by muse, mutect2, varscan2
- HS6ST1 | c.1024G>A p.D342N | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.515); catalogued as rs1252599547, COSV52126541, COSV52128370; called by muse, mutect2, varscan2
- HSP90AB1 | c.52C>T p.Q18* | Nonsense Mutation (SNP) | VAF 54/116 reads (47%) | catalogued as rs765906022, COSV62334504, COSV62336891; called by muse, mutect2, varscan2
- HSPA2 | c.279C>A p.F93L | Missense Mutation (SNP) | VAF 61/151 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99904974; called by muse, mutect2, varscan2
- HTRA2 | c.835C>T p.Q279* | Nonsense Mutation (SNP) | VAF 75/157 reads (48%) | catalogued as COSV51207439; called by muse, mutect2, varscan2
- HUS1 | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 133/247 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.395); catalogued as COSV51838772, COSV99346391; called by muse, mutect2, varscan2
- HUWE1 | c.2972-1G>A p.X991_splice | Splice Site (SNP) | VAF 16/30 reads (53%) | catalogued as COSV99473596; called by muse, mutect2, varscan2
- ICAM3 | c.478G>T p.E160* | Nonsense Mutation (SNP) | VAF 38/174 reads (22%) | catalogued as COSV99349382; called by muse, mutect2, varscan2
- ICAM5 | c.1294G>A p.E432K | Missense Mutation (SNP) | VAF 71/261 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.242); catalogued as COSV99703019; called by muse, mutect2, varscan2
- IDUA | c.1294G>A p.D432N | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.365); catalogued as rs1485492553; called by muse, mutect2, varscan2
- IFIT3 | c.1066G>A p.E356K | Missense Mutation (SNP) | VAF 65/137 reads (47%) | SIFT tolerated (0.53); PolyPhen benign (0.005); catalogued as COSV51079255; called by muse, mutect2, varscan2
- IGF1R | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 60/121 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.209); catalogued as rs757195696, COSV51278725; called by muse, mutect2, varscan2
- IGF1R | c.2431G>A p.E811K | Missense Mutation (SNP) | VAF 31/61 reads (51%) | SIFT tolerated (0.88); PolyPhen benign (0.003); catalogued as COSV51269278, COSV51418210; called by muse, mutect2, varscan2
- IGF2BP3 | c.466G>A p.D156N | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as COSV99033805; called by muse, mutect2, varscan2
- IGHA1 | c.820G>A p.E274K | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.276); catalogued as rs587723177; called by muse, mutect2, varscan2
- IGHD2-2 | c.17A>T p.Y6F | Missense Mutation (SNP) | VAF 26/26 reads (100%) | catalogued as rs535073705; called by mutect2, varscan2
- IGHV3-33 | c.148A>T p.S50C | Missense Mutation (SNP) | VAF 46/112 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.659); catalogued as rs774237271; called by muse, varscan2
- IGLV1-36 | c.164G>T p.W55L | Missense Mutation (SNP) | VAF 114/116 reads (98%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as rs753445068; called by muse, mutect2, varscan2
- IGLV3-10 | c.61T>C p.Y21H | Missense Mutation (SNP) | VAF 35/36 reads (97%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.922); catalogued as rs572588135; called by muse, mutect2, varscan2
- IGLV4-60 | c.205A>G p.M69V | Missense Mutation (SNP) | VAF 76/183 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.063); catalogued as rs769004051; called by muse, mutect2, varscan2
- IGSF3 | c.3160C>G p.R1054G (on ENST00000369486 / NM_001007237.3; = p.R1074G on NM_001542.4) | Missense Mutation (SNP) | VAF 77/163 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.171); catalogued as COSV100605051; called by muse, mutect2, varscan2
- IKZF2 | c.1311G>A p.M437I | Missense Mutation (SNP) | VAF 51/77 reads (66%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as COSV100563286; called by muse, mutect2, varscan2
- IKZF3 | c.639G>C p.Q213H | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53104881; called by muse, mutect2, varscan2
- IL12RB2 | c.2311G>A p.E771K | Missense Mutation (SNP) | VAF 55/127 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.049); catalogued as rs780230506; called by muse, mutect2, varscan2
- IL17RE | c.1142G>T p.R381I | Missense Mutation (SNP) | VAF 26/231 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.243); catalogued as COSV55967485; called by muse, mutect2, varscan2
- IL31RA | c.2114C>T p.S705L | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as rs763337032, COSV61692662; called by muse, mutect2, varscan2
- IMMT | c.2208G>C p.Q736H | Missense Mutation (SNP) | VAF 73/168 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781769634, COSV99606319; called by muse, mutect2, varscan2
- INPP5J | c.158C>T p.S53L | Missense Mutation (SNP) | VAF 119/213 reads (56%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs763939360, COSV100459611; called by muse, mutect2, varscan2
- INVS | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 54/134 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.687); catalogued as rs759684253, COSV99317110; called by muse, mutect2, varscan2
- IQGAP1 | c.1288C>T p.Q430* | Nonsense Mutation (SNP) | VAF 22/44 reads (50%) | catalogued as COSV51585367; called by muse, mutect2, varscan2
- IQGAP1 | c.1609G>A p.E537K | Missense Mutation (SNP) | VAF 45/110 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.272); catalogued as rs1219821145, COSV51581842; called by muse, mutect2, varscan2
- IRF2 | c.610G>A p.E204K | Missense Mutation (SNP) | VAF 46/105 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66929478, COSV66929583; called by muse, mutect2, varscan2
- IRF3 | c.565G>A p.E189K | Missense Mutation (SNP) | VAF 42/81 reads (52%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.761); catalogued as rs947514397; called by muse, mutect2, varscan2
- IRX5 | c.1160C>T p.S387L | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.502); catalogued as rs759550123; called by muse, mutect2, varscan2
- ITGA1 | c.2321G>A p.R774K | Missense Mutation (SNP) | VAF 120/248 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1218196088; called by muse, mutect2, varscan2
- ITGAL | c.3324C>G p.F1108L | Missense Mutation (SNP) | VAF 63/135 reads (47%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.993); catalogued as COSV63322295; called by muse, mutect2, varscan2
- ITGAV | c.1310C>T p.S437L | Missense Mutation (SNP) | VAF 47/101 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.099); catalogued as rs932743686; called by muse, mutect2, varscan2
- ITIH1 | c.1066C>G p.Q356E | Missense Mutation (SNP) | VAF 39/80 reads (49%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as COSV56258734; called by muse, mutect2, varscan2
- ITK | c.1804C>T p.R602W | Missense Mutation (SNP) | VAF 106/234 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781475918, COSV70061653; called by muse, mutect2, varscan2
- ITPRID2 | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.074); catalogued as COSV57471774; called by muse, mutect2, varscan2
- ITSN2 | c.2564C>T p.S855L | Missense Mutation (SNP) | VAF 10/131 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV61947593; called by muse, mutect2
- JADE1 | c.1175C>T p.S392F | Missense Mutation (SNP) | VAF 65/143 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as rs776716046; called by muse, mutect2, varscan2
- KBTBD7 | c.86C>A p.S29* | Nonsense Mutation (SNP) | VAF 38/82 reads (46%) | catalogued as rs779379416, COSV65267116; called by muse, mutect2, varscan2
- KCNH4 | c.1402G>A p.A468T | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1421636700; called by muse, mutect2, varscan2
- KCNQ1 | c.1895G>A p.R632K | Missense Mutation (SNP) | VAF 38/72 reads (53%) | SIFT tolerated (0.62); PolyPhen benign (0.036); catalogued as COSV50103544, COSV50134539; called by muse, mutect2, varscan2
- KCTD3 | c.106C>T p.L36F | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1023686454, COSV52069903; called by muse, mutect2, varscan2
- KDM4C | c.2786G>A p.R929Q | Missense Mutation (SNP) | VAF 39/73 reads (53%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.998); catalogued as rs752244908; called by muse, mutect2, varscan2
- KDM6B | c.2513C>G p.S838C | Missense Mutation (SNP) | VAF 33/127 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.788); catalogued as COSV54679567; called by muse, mutect2, varscan2
- KDM8 | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 69/145 reads (48%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs778456623; called by muse, mutect2, varscan2
- KIAA0100 | c.958C>T p.R320* | Nonsense Mutation (SNP) | VAF 17/68 reads (25%) | catalogued as rs750801718, COSV66495350; called by muse, mutect2, varscan2
- KIAA1549L | c.580C>T p.P194S (on ENST00000321505; = p.P491S on NM_012194.3) | Missense Mutation (SNP) | VAF 54/97 reads (56%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.007); catalogued as COSV55772057; called by muse, mutect2, varscan2
- KIAA1671 | c.709C>T p.R237C | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs1319257470; called by muse, mutect2, varscan2
- KIAA2026 | c.6005C>T p.S2002L | Missense Mutation (SNP) | VAF 138/267 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as rs1304732493, COSV101199013; called by muse, mutect2, varscan2
- KIF13B | c.3809G>A p.R1270K | Missense Mutation (SNP) | VAF 45/102 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101580546, COSV72954750; called by muse, mutect2, varscan2
- KIF21B | c.1049C>T p.S350L | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100143687; called by muse, mutect2, varscan2
- KIF4B | c.1523C>A p.S508Y | Missense Mutation (SNP) | VAF 69/145 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.321); catalogued as COSV70531212; called by muse, mutect2, varscan2
- KIF5C | c.1132G>A p.E378K | Missense Mutation (SNP) | VAF 27/44 reads (61%) | SIFT tolerated (0.56); PolyPhen benign (0.066); catalogued as rs1489265808; called by muse, mutect2, varscan2
- KIRREL2 | c.1723C>T p.R575W | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.53); catalogued as rs753993342; called by muse, mutect2, varscan2
- KLHL32 | c.1253G>A p.R418Q | Missense Mutation (SNP) | VAF 39/80 reads (49%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.842); catalogued as rs764687503, COSV100987308, COSV65112803; called by muse, mutect2, varscan2
- KLK3 | c.568C>T p.Q190* | Nonsense Mutation (SNP) | VAF 52/96 reads (54%) | catalogued as COSV100386056; called by muse, mutect2, varscan2
- KMT2B | c.5743C>T p.R1915C | Missense Mutation (SNP) | VAF 65/154 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs1471456268; called by muse, mutect2, varscan2
- KMT2E | c.3494G>C p.R1165T | Missense Mutation (SNP) | VAF 91/164 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as COSV57569390, COSV57576632; called by muse, mutect2, varscan2
- KRT24 | c.976G>A p.E326K | Missense Mutation (SNP) | VAF 96/320 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as rs771600549; called by muse, mutect2, varscan2
- KRT33A | c.226C>T p.Q76* | Nonsense Mutation (SNP) | VAF 22/74 reads (30%) | catalogued as rs771962096; called by muse, mutect2, varscan2
- KRT7 | c.134C>T p.S45L | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.058); catalogued as COSV59330763; called by muse, mutect2, varscan2
- KRTAP10-12 | c.61G>A p.D21N | Missense Mutation (SNP) | VAF 9/138 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as rs1555950728, COSV59977957; called by muse, mutect2
- KSR2 | c.1210C>T p.R404C | Missense Mutation (SNP) | VAF 88/190 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779409612, COSV56673016; called by muse, mutect2, varscan2
- KYAT3 | c.946C>T p.P316S | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.817); catalogued as COSV99557250; called by muse, mutect2, varscan2
- KYNU | c.1255G>A p.E419K | Missense Mutation (SNP) | VAF 54/107 reads (50%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as rs1220033404; called by muse, mutect2, varscan2
- LANCL2 | c.94G>T p.E32* | Nonsense Mutation (SNP) | VAF 46/113 reads (41%) | catalogued as rs748666611; called by muse, mutect2, varscan2
- LDLR | c.2368C>G p.L790V | Missense Mutation (SNP) | VAF 27/164 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.955); catalogued as rs1252368409; called by muse, mutect2, varscan2
- LDLRAD3 | c.1027G>A p.E343K | Missense Mutation (SNP) | VAF 85/194 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV59684852, COSV59691278; called by muse, mutect2, varscan2
- LEMD3 | c.54C>G p.F18L | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as rs377077013, COSV57648816; called by muse, mutect2, varscan2
- LEPR | c.546G>C p.Q182H | Missense Mutation (SNP) | VAF 45/97 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as COSV60753585; called by muse, mutect2, varscan2
- LEPR | c.2989G>T p.E997* | Nonsense Mutation (SNP) | VAF 48/105 reads (46%) | catalogued as COSV62752809; called by muse, mutect2, varscan2
- LGR4 | c.2546C>T p.S849L | Missense Mutation (SNP) | VAF 115/254 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.086); catalogued as rs949238471; called by muse, mutect2
- LHCGR | c.1955G>A p.R652K | Missense Mutation (SNP) | VAF 196/405 reads (48%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.965); catalogued as rs1558796433; called by muse, mutect2, varscan2
- LINGO2 | c.928C>T p.R310C | Missense Mutation (SNP) | VAF 46/99 reads (46%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.803); catalogued as rs1329891686, COSV58061180; called by muse, mutect2, varscan2
- LMOD3 | c.1012G>A p.E338K | Missense Mutation (SNP) | VAF 116/266 reads (44%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.489); catalogued as COSV70456354; called by muse, mutect2, varscan2
- LONRF1 | c.1063C>T p.H355Y | Missense Mutation (SNP) | VAF 170/369 reads (46%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV68036268; called by muse, mutect2, varscan2
- LPIN2 | c.591-1G>T p.X197_splice | Splice Site (SNP) | VAF 28/73 reads (38%) | catalogued as COSV55242491; called by muse, mutect2, varscan2
- LRIT3 | c.1073C>T p.S358F | Missense Mutation (SNP) | VAF 88/207 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.085); catalogued as rs1175352567; called by muse, mutect2, varscan2
- LRP11 | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.06); catalogued as rs982298320; called by muse, mutect2, varscan2
- LRP1B | c.10042G>A p.E3348K | Missense Mutation (SNP) | VAF 98/228 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101260931; called by muse, mutect2, varscan2
- LRP6 | c.1708G>C p.D570H | Missense Mutation (SNP) | VAF 66/149 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV99742657; called by muse, mutect2, varscan2
- LRRC14B | c.1441G>A p.D481N | Missense Mutation (SNP) | VAF 102/204 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57256454, COSV57257703; called by muse, mutect2, varscan2
- LRRC24 | c.1444G>A p.E482K | Missense Mutation (SNP) | VAF 70/123 reads (57%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.058); catalogued as COSV52879846; called by muse, mutect2, varscan2
- LRRC36 | c.1659C>T p.L553= | Splice Region (SNP) | VAF 91/264 reads (34%) | catalogued as rs988545000, COSV99338502; called by muse, mutect2, varscan2
- LRRC53 | c.1952C>T p.S651L | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1298549578; called by muse, mutect2, varscan2
- LRWD1 | c.1437G>C p.K479N | Missense Mutation (SNP) | VAF 47/82 reads (57%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.879); catalogued as COSV53000983; called by muse, mutect2, varscan2
- LTBP3 | c.3115G>A p.E1039K | Missense Mutation (SNP) | VAF 59/117 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54215314; called by muse, mutect2, varscan2
- LYG2 | c.313G>T p.E105* | Nonsense Mutation (SNP) | VAF 26/58 reads (45%) | catalogued as COSV60715256; called by muse, varscan2
- LYVE1 | c.890C>T p.S297L | Missense Mutation (SNP) | VAF 183/396 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.212); catalogued as COSV99811135; called by muse, mutect2, varscan2
- LZTS1 | c.1505G>A p.R502Q | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.843); catalogued as rs753024731, COSV56116475; called by muse, mutect2, varscan2
- MADD | c.4766G>A p.R1589Q | Missense Mutation (SNP) | VAF 63/127 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.242); catalogued as rs775038699; called by muse, mutect2, varscan2
- MAEA | c.758C>T p.P253L (on ENST00000303400 / NM_001017405.3; = p.P212L on NM_005882.5) | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.895); catalogued as COSV99295614; called by muse, mutect2
- MAGIX | c.250C>T p.H84Y | Missense Mutation (SNP) | VAF 178/355 reads (50%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.946); catalogued as COSV100891942; called by muse, mutect2, varscan2
- MAMDC4 | c.2395G>A p.D799N (on ENST00000445819; = p.D720N on NM_206920.3) | Missense Mutation (SNP) | VAF 63/128 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768076587; called by muse, mutect2, varscan2
- MAP1A | c.1132G>A p.E378K | Missense Mutation (SNP) | VAF 67/134 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.88); catalogued as COSV100289143, COSV100289259; called by muse, mutect2, varscan2
- MAP3K1 | c.3058C>T p.Q1020* | Nonsense Mutation (SNP) | VAF 146/288 reads (51%) | catalogued as COSV68125035; called by muse, mutect2, varscan2
- MAP3K10 | c.911G>A p.R304H | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.305); catalogued as rs535058788; called by muse, mutect2, varscan2
- MAPK8IP3 | c.1998G>A p.W666* | Nonsense Mutation (SNP) | VAF 27/64 reads (42%) | catalogued as rs1227672260; called by muse, mutect2, varscan2
- MAPT | c.37G>A p.D13N | Missense Mutation (SNP) | VAF 70/271 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs773820376, COSV52238204; called by muse, mutect2
- MAS1L | c.707C>T p.S236L | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs753599895, COSV65808859, COSV65809382; called by muse, mutect2, varscan2
- MAST1 | c.4511C>T p.S1504F | Missense Mutation (SNP) | VAF 30/149 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1364345130; called by muse, mutect2, varscan2
- MAST3 | c.2079G>C p.E693D | Missense Mutation (SNP) | VAF 61/313 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.143); catalogued as COSV53217110; called by muse, mutect2, varscan2
- MASTL | c.2069C>T p.S690L | Missense Mutation (SNP) | VAF 71/153 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1195924844, COSV60912599; called by muse, mutect2, varscan2
- MBD6 | c.1771G>A p.E591K | Missense Mutation (SNP) | VAF 110/232 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.201); catalogued as rs1457858834; called by muse, mutect2, varscan2
- MCHR2 | c.284G>A p.R95Q | Missense Mutation (SNP) | VAF 51/96 reads (53%) | SIFT tolerated (0.45); PolyPhen benign (0.009); catalogued as rs1015907823, COSV56002006, COSV99912673; called by muse, mutect2, varscan2
- MCM3 | c.1087C>T p.Q363* (on ENST00000229854 / NM_001366374.2; = p.Q353* on NM_002388.6 and 5 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 12/28 reads (43%) | catalogued as COSV57716631, COSV57716844; called by muse, varscan2
- MCM3 | c.37G>A p.E13K | Missense Mutation (SNP) | VAF 111/235 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.14); catalogued as rs1377178069; called by muse, mutect2, varscan2
- MCM3AP | c.4747G>A p.E1583K | Missense Mutation (SNP) | VAF 59/155 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as rs1569054578; called by muse, mutect2, varscan2
- MCTP1 | c.1025C>T p.S342L | Missense Mutation (SNP) | VAF 163/358 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775002256; called by muse, mutect2, varscan2
- MDN1 | c.11803C>T p.R3935C | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1256610676, COSV65516337, COSV65521088; called by muse, mutect2, varscan2
- ME2 | c.985G>C p.E329Q | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.045); catalogued as COSV100360761; called by muse, mutect2, varscan2
- MECR | c.700G>C p.E234Q | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as COSV55285255; called by muse, mutect2, varscan2
- MED1 | c.1901C>T p.S634L | Missense Mutation (SNP) | VAF 64/193 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as rs769487771, COSV56122354; called by muse, mutect2, varscan2
- MED12 | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 41/75 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.298); catalogued as COSV61342468; called by muse, mutect2, varscan2
- MESP2 | c.730G>C p.D244H | Missense Mutation (SNP) | VAF 80/171 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV100510754; called by muse, mutect2, varscan2
- METTL23 | c.323-3C>T | Splice Region (SNP) | VAF 16/114 reads (14%) | catalogued as rs751325951, COSV57971591; called by muse, mutect2, varscan2
- MFAP3 | c.757G>C p.E253Q | Missense Mutation (SNP) | VAF 66/154 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59456655; called by muse, mutect2, varscan2
- MFN1 | c.1781G>C p.R594T | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as COSV99764269; called by muse, mutect2, varscan2
- MFSD3 | c.145C>T p.P49S | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56742050; called by muse, mutect2, varscan2
- MGA | c.3316C>T p.R1106* | Nonsense Mutation (SNP) | VAF 36/80 reads (45%) | catalogued as COSV54960000; called by muse, mutect2, varscan2
- MGA | c.6665C>G p.S2222C (on ENST00000219905 / NM_001164273.1; = p.S2013C on NM_001080541.2) | Missense Mutation (SNP) | VAF 119/253 reads (47%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.41); catalogued as COSV99581877; called by muse, mutect2, varscan2
- MGST3 | c.250C>A p.R84S | Missense Mutation (SNP) | VAF 78/183 reads (43%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.925); catalogued as COSV100903359; called by muse, mutect2, varscan2
- MIA3 | c.1517C>G p.S506C | Missense Mutation (SNP) | VAF 59/132 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); catalogued as rs746528728; called by muse, mutect2, varscan2
- MICAL1 | c.1615G>T p.D539Y | Missense Mutation (SNP) | VAF 52/108 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV57805704, COSV57806311; called by muse, mutect2, varscan2
- MIOS | c.2542G>C p.E848Q | Missense Mutation (SNP) | VAF 110/239 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV60770669; called by muse, mutect2, varscan2
- MKS1 | c.178C>T p.Q60* | Nonsense Mutation (SNP) | VAF 43/103 reads (42%) | catalogued as COSV100439615, COSV58303587; called by muse, mutect2, varscan2
- MLYCD | c.315G>C p.Q105H | Missense Mutation (SNP) | VAF 43/67 reads (64%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs1446247481; called by muse, mutect2, varscan2
- MMP3 | c.1237G>A p.E413K | Missense Mutation (SNP) | VAF 8/199 reads (4%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as rs782608620; called by muse, mutect2
- MNT | c.295C>G p.Q99E | Missense Mutation (SNP) | VAF 61/89 reads (69%) | SIFT tolerated (0.65); PolyPhen benign (0.264); catalogued as COSV51512720; called by muse, mutect2, varscan2
- MPI | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 4/87 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100086248; called by muse, mutect2
- MPND | c.1288G>A p.E430K | Missense Mutation (SNP) | VAF 31/136 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.012); catalogued as rs1365416007, COSV99515420; called by muse, mutect2, varscan2
- MPP7 | c.776G>T p.G259V | Missense Mutation (SNP) | VAF 53/124 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100517832; called by muse, mutect2, varscan2
- MRPL20 | c.321C>G p.I107M | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs201348345, COSV61223980; called by muse, mutect2, varscan2
- MRPL38 | c.224G>A p.R75Q | Missense Mutation (SNP) | VAF 66/102 reads (65%) | SIFT tolerated (0.05); PolyPhen benign (0.031); catalogued as rs1220338792; called by muse, mutect2
- MRPL58 | c.38G>A p.R13Q | Missense Mutation (SNP) | VAF 34/127 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.521); catalogued as rs754233014; called by muse, mutect2, varscan2
- MS4A3 | c.386C>T p.A129V | Missense Mutation (SNP) | VAF 105/212 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.807); catalogued as COSV53935897, COSV53936514; called by muse, mutect2, varscan2
- MSH2 | c.947C>T p.S316F | Missense Mutation (SNP) | VAF 65/142 reads (46%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.873); catalogued as rs876660241; called by muse, mutect2, varscan2
- MTHFD1L | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 90/168 reads (54%) | SIFT tolerated (0.57); PolyPhen benign (0.005); catalogued as rs1157955113; called by muse, mutect2, varscan2
- MTMR2 | c.431G>A p.R144Q | Missense Mutation (SNP) | VAF 56/112 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.066); catalogued as rs1555065007, COSV100656567; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MTNR1B | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs1217966168; called by muse, mutect2, varscan2
- MTR | c.3208G>A p.E1070K | Missense Mutation (SNP) | VAF 88/157 reads (56%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.786); catalogued as rs1318765706, COSV63965034, COSV63965336; called by muse, mutect2, varscan2
- MUC12 | c.2243C>T p.S748F (on ENST00000379442; = p.S605F on NM_001164462.1) | Missense Mutation (SNP) | VAF 50/371 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.496); catalogued as rs1462447312; called by muse, mutect2, varscan2
- MUC16 | c.19406C>T p.S6469L | Missense Mutation (SNP) | VAF 41/203 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.024); catalogued as rs1442384354; called by muse, varscan2
- MUC16 | c.5455C>T p.P1819S | Missense Mutation (SNP) | VAF 68/278 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as rs377657259; called by muse, mutect2, varscan2
- MUC4 | c.6308C>T p.S2103F | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.496); catalogued as rs574704523; called by muse, mutect2
- MUC5B | c.14789G>C p.R4930T | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as COSV101500378; called by muse, mutect2, varscan2
- MYBPH | c.961C>T p.H321Y | Missense Mutation (SNP) | VAF 74/140 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs753347776; called by muse, mutect2, varscan2
- MYH1 | c.2797G>A p.E933K | Missense Mutation (SNP) | VAF 60/170 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV99877247; called by muse, mutect2, varscan2
- MYH10 | c.5029G>C p.E1677Q | Missense Mutation (SNP) | VAF 95/160 reads (59%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV52597493; called by muse, mutect2, varscan2
- MYH2 | c.4681G>A p.E1561K | Missense Mutation (SNP) | VAF 99/345 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); catalogued as rs748063533, COSV99820365; called by muse, mutect2, varscan2
- MYH2 | c.4294G>A p.E1432K | Missense Mutation (SNP) | VAF 139/222 reads (63%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.746); catalogued as rs747081221, COSV55435723, COSV55437149; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH7 | c.4660G>A p.E1554K | Missense Mutation (SNP) | VAF 46/89 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.61); catalogued as rs142694139; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO1F | c.874G>A p.G292R | Missense Mutation (SNP) | VAF 64/286 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.581); catalogued as rs751357754, COSV57799495; called by muse, varscan2
- MYO1H | c.366G>C p.E122D | Missense Mutation (SNP) | VAF 87/184 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs142805645, COSV60450625; called by muse, mutect2, varscan2
- NAA25 | c.2300C>T p.S767F | Missense Mutation (SNP) | VAF 98/187 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.293); catalogued as COSV99928083; called by muse, mutect2, varscan2
- NANOS3 | c.301G>A p.E101K (on ENST00000397555; = p.E120K on NM_001098622.2) | Missense Mutation (SNP) | VAF 72/304 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.42); catalogued as rs1286391250, CM147813; called by muse, mutect2, varscan2
- NAV3 | c.5900G>A p.R1967Q (on ENST00000397909 / NM_001024383.2; = p.R1945Q on NM_014903.6) | Missense Mutation (SNP) | VAF 38/73 reads (52%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.996); catalogued as rs748365484, COSV57061306; called by muse, mutect2, varscan2
- NBEAL1 | c.5430G>A p.M1810I | Missense Mutation (SNP) | VAF 74/187 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV71375594; called by muse, mutect2, varscan2
- NBEAL1 | c.5869C>T p.H1957Y | Missense Mutation (SNP) | VAF 53/117 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.033); catalogued as COSV68915730; called by muse, mutect2, varscan2
- NBEAL2 | c.5768C>T p.S1923L | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.155); catalogued as rs1437599525; called by muse, mutect2, varscan2
- NCKAP1 | c.2482G>C p.E828Q | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.887); catalogued as COSV62940495; called by muse, mutect2, varscan2
- NCKAP5 | c.4417G>A p.E1473K | Missense Mutation (SNP) | VAF 6/125 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs911991502, COSV58464584; called by muse, mutect2
- NCKIPSD | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 44/87 reads (51%) | SIFT tolerated (0.14); PolyPhen benign (0.395); catalogued as rs1164539402; called by muse, mutect2, varscan2
- NCOA1 | c.1759G>A p.E587K | Missense Mutation (SNP) | VAF 41/100 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.874); catalogued as COSV56047618; called by muse, mutect2, varscan2
- NCOR1 | c.5374C>T p.Q1792* | Nonsense Mutation (SNP) | VAF 116/182 reads (64%) | catalogued as COSV51996750; called by muse, mutect2, varscan2
- NEDD4L | c.52G>C p.E18Q | Missense Mutation (SNP) | VAF 59/131 reads (45%) | SIFT tolerated (0.33); PolyPhen benign (0.269); catalogued as COSV56839369; called by muse, mutect2, varscan2
- NEIL2 | c.489G>A p.P163= | Splice Region (SNP) | VAF 74/149 reads (50%) | catalogued as rs780941719; called by muse, mutect2, varscan2
- NEK11 | c.760G>A p.E254K | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT tolerated (0.27); PolyPhen benign (0.006); catalogued as COSV63581230; called by muse, mutect2, varscan2
- NETO2 | c.176C>T p.S59L | Missense Mutation (SNP) | VAF 47/152 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.073); catalogued as rs751020123, COSV57452701; called by muse, mutect2, varscan2
- NEURL4 | c.2909C>T p.S970F | Missense Mutation (SNP) | VAF 120/193 reads (62%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as COSV59747742; called by muse, mutect2, varscan2
- NEUROD1 | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 56/118 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as rs773755753, COSV54548434; called by muse, mutect2, varscan2
- NF1 | c.1939C>T p.H647Y | Missense Mutation (SNP) | VAF 61/245 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.031); catalogued as rs776251084, COSV62213849; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NF1 | c.5545G>C p.D1849H (on ENST00000358273 / NM_001042492.3; = p.D1828H on NM_000267.3) | Missense Mutation (SNP) | VAF 42/123 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV62197537, COSV62213806; called by muse, mutect2, varscan2
- NFE2 | c.238C>T p.P80S | Missense Mutation (SNP) | VAF 55/117 reads (47%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs764697633; called by muse, mutect2, varscan2
- NFYA | c.1012G>A p.E338K | Missense Mutation (SNP) | VAF 113/271 reads (42%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.03); catalogued as COSV100399588; called by muse, mutect2, varscan2
- NIBAN1 | c.1108G>A p.E370K | Missense Mutation (SNP) | VAF 54/109 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as rs1195867749; called by muse, mutect2, varscan2
- NIBAN3 | c.325C>T p.R109W | Missense Mutation (SNP) | VAF 60/219 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as rs536652149, COSV56308194; called by muse, mutect2, varscan2
- NIBAN3 | c.1545C>G p.F515L | Missense Mutation (SNP) | VAF 38/183 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.051); catalogued as rs776045006; called by muse, mutect2, varscan2
- NID2 | c.1321G>A p.E441K | Missense Mutation (SNP) | VAF 48/96 reads (50%) | SIFT tolerated (0.74); PolyPhen benign (0.036); catalogued as rs947918363, COSV53498394; called by muse, mutect2, varscan2
- NIPBL | c.4891C>G p.Q1631E | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT tolerated (0.39); PolyPhen benign (0.027); catalogued as COSV56951644; called by muse, mutect2, varscan2
- NKAPL | c.959G>A p.R320Q | Missense Mutation (SNP) | VAF 108/224 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.894); catalogued as rs61737341, COSV100642533; called by muse, mutect2, varscan2
- NKX3-1 | c.457G>A p.E153K | Missense Mutation (SNP) | VAF 79/217 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66512085, COSV66512530; called by muse, mutect2, varscan2
- NKX3-2 | c.306G>C p.E102D | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.63); PolyPhen benign (0.039); catalogued as rs771586473; called by muse, varscan2
- NLRC5 | c.2662C>T p.R888W | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs780457099; called by muse, mutect2, varscan2
- NLRP6 | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.113); catalogued as rs1387700818, COSV100381210; called by muse, mutect2, varscan2
- NOP16 | c.346A>G p.I116V | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.994); catalogued as rs1490053833; called by muse, mutect2, varscan2
- NOP56 | c.1645G>A p.E549K | Missense Mutation (SNP) | VAF 7/124 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.971); catalogued as COSV61389771; called by muse, mutect2
- NOS3 | c.208C>T p.R70C | Missense Mutation (SNP) | VAF 59/191 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs772393632; called by muse, mutect2, varscan2
- NOS3 | c.2162G>C p.R721P | Missense Mutation (SNP) | VAF 33/124 reads (27%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as COSV52493644; called by muse, mutect2, varscan2
- NOTCH4 | c.4155G>A p.M1385I | Missense Mutation (SNP) | VAF 67/124 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.065); catalogued as COSV100901114; called by muse, mutect2, varscan2
- NOXRED1 | c.686G>A p.G229E | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.298); catalogued as rs759510067; called by muse, mutect2, varscan2
- NPR3 | c.950C>T p.S317L | Missense Mutation (SNP) | VAF 47/106 reads (44%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.981); catalogued as rs780681861; called by muse, mutect2, varscan2
- NR2F6 | c.240C>A p.F80L | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV52244529; called by muse, mutect2, varscan2
- NRXN3 | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT tolerated, low confidence (0.35); PolyPhen possibly damaging (0.692); catalogued as rs752457620; called by muse, mutect2
- NSD3 | c.343G>C p.E115Q | Missense Mutation (SNP) | VAF 62/126 reads (49%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.778); catalogued as rs776051289; called by muse, mutect2, varscan2
- NSUN3 | c.968G>A p.W323* | Nonsense Mutation (SNP) | VAF 133/275 reads (48%) | catalogued as rs369273000; called by muse, mutect2, varscan2
- NTN3 | c.193C>T p.R65W | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs1248083027; called by muse, mutect2, varscan2
- NUBP1 | c.717+3G>A | Splice Region (SNP) | VAF 8/39 reads (21%) | catalogued as rs755223093; called by muse, mutect2, varscan2
- NUDT15 | c.256G>A p.E86K | Missense Mutation (SNP) | VAF 65/132 reads (49%) | SIFT tolerated (0.86); PolyPhen benign (0.003); catalogued as COSV51642320; called by muse, mutect2, varscan2
- NUP153 | c.4292C>T p.S1431L | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.779); catalogued as rs767521864; called by muse, mutect2, varscan2
- NUP88 | c.2052G>A p.M684I | Missense Mutation (SNP) | VAF 52/175 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.06); catalogued as COSV99336430; called by muse, mutect2, varscan2
- NWD2 | c.5132C>G p.S1711C | Missense Mutation (SNP) | VAF 69/140 reads (49%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.066); catalogued as rs1307395774; called by muse, mutect2, varscan2
- OAS1 | c.1038+3G>A | Splice Region (SNP) | VAF 146/298 reads (49%) | catalogued as COSV52537975; called by muse, varscan2
- OBSL1 | c.4227G>C p.Q1409H | Missense Mutation (SNP) | VAF 119/222 reads (54%) | SIFT deleterious (0.05); PolyPhen benign (0.022); catalogued as rs757167625; called by muse, mutect2, varscan2
- OCRL | c.2122G>C p.D708H | Missense Mutation (SNP) | VAF 67/159 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV63980868; called by muse, mutect2, varscan2
- OGN | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated (0.22); PolyPhen benign (0.086); catalogued as rs770950188; called by muse, mutect2, varscan2
- OR1S1 | c.508C>G p.L170V | Missense Mutation (SNP) | VAF 60/125 reads (48%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.487); catalogued as rs149752818; called by muse, mutect2, varscan2
- OR4D2 | c.347C>T p.S116L | Missense Mutation (SNP) | VAF 144/226 reads (64%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.703); catalogued as rs752659182; called by muse, varscan2
- OR4E2 | c.676C>T p.R226* | Nonsense Mutation (SNP) | VAF 64/141 reads (45%) | catalogued as rs368987419; called by muse, mutect2, varscan2
- OR4F15 | c.287G>A p.G96E | Missense Mutation (SNP) | VAF 92/189 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.458); catalogued as rs749278161, COSV59968676; called by muse, mutect2, varscan2
- OR52E8 | c.914G>C p.R305P | Missense Mutation (SNP) | VAF 165/349 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as rs1292815213; called by muse, mutect2, varscan2
- OTOF | c.2107C>G p.L703V | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); catalogued as COSV99717519; called by muse, mutect2, varscan2
- OTULINL | c.650G>C p.R217T | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.109); catalogued as COSV99947236; called by muse, mutect2, varscan2
- OXSR1 | c.1189G>A p.G397R | Missense Mutation (SNP) | VAF 8/156 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.317); catalogued as COSV100309394; called by muse, mutect2
- PADI2 | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 60/150 reads (40%) | SIFT tolerated (0.37); PolyPhen benign (0.011); catalogued as rs201884124, COSV64946580; called by muse, mutect2, varscan2
- PANX3 | c.1015G>A p.E339K | Missense Mutation (SNP) | VAF 63/130 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as rs1191001163, COSV52511607; called by muse, mutect2, varscan2
- PARD3B | c.2183C>T p.S728L | Missense Mutation (SNP) | VAF 65/147 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs747892833; called by muse, mutect2, varscan2
- PBXIP1 | c.496G>A p.E166K | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.45); PolyPhen benign (0.124); catalogued as rs751951283, COSV63777068; called by muse, mutect2, varscan2
- PCDHA2 | c.1792G>T p.D598Y | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs782228183; called by muse, mutect2, varscan2
- PCDHB10 | c.865C>G p.R289G | Missense Mutation (SNP) | VAF 54/134 reads (40%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.604); catalogued as COSV53378155, COSV53382241; called by muse, mutect2, varscan2
- PCDHGA3 | c.2056G>A p.D686N | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.009); catalogued as COSV53971283; called by muse, mutect2, varscan2
- PCLO | c.14689C>T p.R4897C | Missense Mutation (SNP) | VAF 125/208 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100429073; called by muse, mutect2, varscan2
- PCNT | c.23G>A p.R8Q | Missense Mutation (SNP) | VAF 65/127 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1192843444; called by muse, mutect2, varscan2
- PCSK2 | c.167G>A p.G56E | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.045); catalogued as rs746184772; called by muse, mutect2, varscan2
- PCSK5 | c.2627G>A p.G876E | Missense Mutation (SNP) | VAF 43/91 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.485); catalogued as rs1255192943, COSV70450751; called by muse, mutect2, varscan2
- PDE11A | c.2248C>T p.H750Y | Missense Mutation (SNP) | VAF 47/90 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as COSV53706395; called by muse, mutect2, varscan2
- PDE6B | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs1302387853, COSV55330058; called by muse, mutect2, varscan2
- PDK4 | c.38C>T p.S13L | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0.024); catalogued as COSV50010361; called by muse, mutect2, varscan2
- PERM1 | c.1049C>T p.S350F | Missense Mutation (SNP) | VAF 38/77 reads (49%) | SIFT tolerated (0.15); PolyPhen benign (0.051); catalogued as rs1294562586; called by muse, mutect2, varscan2
- PEX19 | c.745G>C p.E249Q | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.85); catalogued as COSV63619191, COSV63619406; called by muse, mutect2, varscan2
- PGAM4 | c.48G>A p.W16* | Nonsense Mutation (SNP) | VAF 14/29 reads (48%) | catalogued as COSV58452445; called by muse, mutect2, varscan2
- PGM2 | c.1371G>C p.K457N | Missense Mutation (SNP) | VAF 76/176 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.035); catalogued as COSV67938294; called by muse, mutect2, varscan2
- PGR | c.2241G>C p.Q747H | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99679420; called by muse, mutect2, varscan2
- PHC1 | c.2242G>C p.E748Q | Missense Mutation (SNP) | VAF 119/252 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV70418806; called by muse, mutect2, varscan2
- PHIP | c.5242G>A p.D1748N | Missense Mutation (SNP) | VAF 113/245 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.125); catalogued as COSV99244248; called by muse, mutect2, varscan2
- PHKB | c.1090G>A p.E364K | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs371296953, CM117239, COSV54520479; called by muse, mutect2, varscan2
- PIDD1 | c.718C>T p.R240W | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.761); catalogued as rs777494501, COSV61706681; called by muse, mutect2
- PIP4P2 | c.656G>A p.R219Q | Missense Mutation (SNP) | VAF 170/339 reads (50%) | SIFT tolerated (0.61); PolyPhen benign (0.121); catalogued as rs749313481, COSV53439729; called by muse, mutect2, varscan2
- PKD1L3 | c.2986C>G p.L996V | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.65); PolyPhen benign (0.031); catalogued as COSV58667244; called by muse, mutect2, varscan2
- PKN2 | c.2821G>A p.E941K | Missense Mutation (SNP) | VAF 124/249 reads (50%) | SIFT tolerated (0.2); PolyPhen benign (0.433); catalogued as COSV65142562; called by muse, mutect2, varscan2
- PKP2 | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); catalogued as rs754791731; called by muse, varscan2
- PLCH1 | c.736-1G>A p.X246_splice (on ENST00000340059 / NM_001130960.2; = p.X258_splice on NM_014996.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 34/65 reads (52%) | catalogued as COSV58199801; called by muse, mutect2, varscan2
- PLD6 | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.054); catalogued as COSV58634475; called by muse, mutect2, varscan2
- PLEC | c.13517C>T p.S4506L (on ENST00000322810 / NM_201380.4; = p.S4396L on NM_000445.5) | Missense Mutation (SNP) | VAF 45/104 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1554669959; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLEKHG4 | c.953C>T p.S318L | Missense Mutation (SNP) | VAF 58/147 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs770409263, COSV100846512; called by muse, mutect2, varscan2
- PLEKHH1 | c.3969G>A p.M1323I | Missense Mutation (SNP) | VAF 62/178 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV53614949; called by muse, mutect2, varscan2
- PLK1 | c.70G>A p.G24R | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.091); catalogued as COSV100267181; called by muse, mutect2, varscan2
- PLK1 | c.772G>C p.E258Q | Missense Mutation (SNP) | VAF 33/61 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV55624830; called by muse, mutect2, varscan2
- PLOD2 | c.1359-1G>A p.X453_splice | Splice Site (SNP) | VAF 20/40 reads (50%) | catalogued as rs1436424588; called by muse, mutect2
- PLXNA1 | c.5509G>A p.E1837K | Missense Mutation (SNP) | VAF 86/179 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.371); catalogued as COSV52522626; called by muse, mutect2, varscan2
- PLXND1 | c.4880C>T p.S1627L | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100140329; called by muse, mutect2, varscan2
- PNPLA8 | c.2334C>G p.F778L | Missense Mutation (SNP) | VAF 101/305 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.254); catalogued as COSV57551789; called by muse, mutect2, varscan2
- POC1B | c.311C>T p.P104L | Missense Mutation (SNP) | VAF 80/177 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.778); catalogued as rs1391093965; called by muse, mutect2, varscan2
- POC5 | c.106C>T p.H36Y (on ENST00000428202 / NM_001099271.2; = p.H11Y on NM_152408.2) | Missense Mutation (SNP) | VAF 68/159 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.074); catalogued as rs779825020, COSV100994336, COSV104431542; called by muse, mutect2, varscan2
- POU3F2 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 37/70 reads (53%) | SIFT tolerated (0.08); PolyPhen benign (0.035); catalogued as COSV100099413, COSV100099524, COSV60409436; called by muse, mutect2, varscan2
- PPARG | c.1154G>A p.R385Q (on ENST00000287820 / NM_015869.5; = p.R355Q on NM_005037.7) | Missense Mutation (SNP) | VAF 93/182 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs140204299; called by muse, mutect2, varscan2
- PPFIBP1 | c.889G>A p.E297K (on ENST00000318304 / NM_177444.3; = p.E266K on NM_003622.4) | Missense Mutation (SNP) | VAF 71/141 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.15); catalogued as rs750525684; called by muse, mutect2, varscan2
- PPP1R15B | c.1523C>T p.S508F | Missense Mutation (SNP) | VAF 59/126 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.813); catalogued as COSV65815677; called by muse, mutect2, varscan2
- PPP1R21 | c.290C>T p.S97F | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as rs774078646; called by muse, mutect2, varscan2
- PPP1R3G | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 37/69 reads (54%) | SIFT tolerated (0.1); PolyPhen benign (0.018); catalogued as rs1272720855; called by muse, mutect2, varscan2
- PPP3CA | c.415C>T p.L139F | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.7); PolyPhen benign (0.007); catalogued as COSV100547920; called by muse, mutect2, varscan2
- PRDM15 | c.1253C>G p.S418* | Nonsense Mutation (SNP) | VAF 22/40 reads (55%) | catalogued as rs750887499; called by muse, mutect2, varscan2
- PRG3 | c.208C>G p.Q70E | Missense Mutation (SNP) | VAF 92/222 reads (41%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as rs376341740; called by muse, mutect2, varscan2
- PRKAG3 | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV52103027, COSV99291961; called by muse, mutect2, varscan2
- PRKCQ | c.787G>T p.D263Y | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV54106579; called by muse, mutect2, varscan2
- PRKD2 | c.671G>A p.R224H | Missense Mutation (SNP) | VAF 70/149 reads (47%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.674); catalogued as rs752855161, COSV52186092; called by muse, mutect2
- PRKRA | c.25G>A p.E9K | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0.001); catalogued as rs1050726687; called by mutect2, varscan2
- PRKRIP1 | c.172C>T p.R58* | Nonsense Mutation (SNP) | VAF 89/309 reads (29%) | catalogued as rs1554570588; called by muse, mutect2, varscan2
- PRR36 | c.3601G>A p.E1201K | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.87); catalogued as rs1348637689; called by muse, mutect2, varscan2
- PRRC2C | c.4637C>T p.S1546F (on ENST00000367742; = p.S1544F on NM_015172.4) | Missense Mutation (SNP) | VAF 90/218 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as rs925406195; called by muse, mutect2, varscan2
- PSG1 | c.435G>C p.E145D | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV54954385, COSV99739456; called by muse, mutect2, varscan2
- PSPN | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 22/382 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.018); catalogued as rs771877984; called by muse, mutect2
- PTGER2 | c.143G>A p.R48H | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT tolerated (0.54); PolyPhen benign (0.014); catalogued as rs768541652; called by muse, mutect2, varscan2
- PTGER4 | c.482C>T p.S161L | Missense Mutation (SNP) | VAF 79/180 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0.067); catalogued as COSV100201480, COSV56721887; called by muse, mutect2, varscan2
- PTK2B | c.2710G>A p.E904K | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs373751030; called by muse, mutect2, varscan2
- PTOV1 | c.517G>A p.D173N | Missense Mutation (SNP) | VAF 49/97 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.414); catalogued as rs1194745078, COSV55590668; called by muse, mutect2, varscan2
- PTPDC1 | c.832G>A p.E278K (on ENST00000375360 / NM_177995.3; = p.E330K on NM_152422.4) | Missense Mutation (SNP) | VAF 58/137 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56621036; called by muse, mutect2, varscan2
- PTPRB | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 63/128 reads (49%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.053); catalogued as COSV51730492; called by muse, mutect2, varscan2
- PTPRJ | c.751C>G p.Q251E | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.105); catalogued as rs1432810307; called by muse, mutect2
- PTPRN2 | c.1816C>T p.Q606* | Nonsense Mutation (SNP) | VAF 37/75 reads (49%) | catalogued as COSV67033734; called by muse, mutect2, varscan2
- PTPRS | c.715G>A p.E239K | Missense Mutation (SNP) | VAF 47/172 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as rs990860881; called by muse, mutect2, varscan2
- PWWP3B | c.1117G>A p.E373K | Missense Mutation (SNP) | VAF 85/204 reads (42%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.526); catalogued as rs780973655; called by muse, mutect2, varscan2
- PYROXD1 | c.1390G>A p.E464K | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); catalogued as COSV99556501; called by muse, mutect2, varscan2
- QSER1 | c.319G>A p.G107R (on ENST00000399302; = p.G236R on NM_001076786.3) | Missense Mutation (SNP) | VAF 88/192 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); catalogued as rs1163610241; called by muse, mutect2, varscan2
- RAB11FIP4 | c.564-3C>T | Splice Region (SNP) | VAF 103/151 reads (68%) | catalogued as rs772976771, COSV100365050, COSV57928854; called by muse, mutect2, varscan2
- RAB44 | c.52C>T p.R18W | Missense Mutation (SNP) | VAF 44/91 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750765597; called by muse, mutect2, varscan2
- RAD54L2 | c.4378G>A p.D1460N | Missense Mutation (SNP) | VAF 58/121 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV56579019; called by muse, mutect2, varscan2
- RAI14 | c.737-1G>A p.X246_splice | Splice Site (SNP) | VAF 13/34 reads (38%) | catalogued as COSV54297212; called by muse, mutect2, varscan2
- RAPGEF5 | c.503C>G p.S168* (on ENST00000401957 / NM_001367602.2; = p.S471* on NM_012294.5) | Nonsense Mutation (SNP) | VAF 53/105 reads (50%) | catalogued as COSV59786652; called by muse, mutect2, varscan2
- RARS2 | c.16C>T p.R6C | Missense Mutation (SNP) | VAF 49/78 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as rs201899366, COSV57638114, COSV57641021; called by muse, mutect2, varscan2
- RB1CC1 | c.2734G>A p.E912K | Missense Mutation (SNP) | VAF 72/170 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.985); catalogued as COSV50271853; called by muse, mutect2, varscan2
- RCN3 | c.307C>G p.R103G | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.308); catalogued as COSV54541357; called by muse, mutect2, varscan2
- RFXANK | c.713-5C>G | Splice Region (SNP) | VAF 41/776 reads (5%) | catalogued as COSV100284379; called by muse, mutect2
- RGS12 | c.1974C>G p.I658M | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0.075); catalogued as COSV60676345; called by muse, mutect2, varscan2
- RHAG | c.345G>A p.M115I | Missense Mutation (SNP) | VAF 90/178 reads (51%) | SIFT tolerated (0.12); PolyPhen benign (0.05); catalogued as rs557741497, COSV57703396; called by muse, mutect2, varscan2
- RIOX1 | c.1542G>C p.L514F | Missense Mutation (SNP) | VAF 63/127 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.665); catalogued as COSV100408023; called by muse, varscan2
- RIOX1 | c.1600G>A p.E534K | Missense Mutation (SNP) | VAF 43/96 reads (45%) | SIFT tolerated (0.46); PolyPhen benign (0.005); catalogued as COSV58374852; called by muse, varscan2
- RLBP1 | c.821C>T p.S274F | Missense Mutation (SNP) | VAF 56/127 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.216); catalogued as rs1271661344; called by muse, mutect2, varscan2
- RLBP1 | c.790G>A p.E264K | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated (0.45); PolyPhen benign (0.071); catalogued as rs1342712582; called by muse, mutect2, varscan2
- RNF19B | c.754G>A p.D252N | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); catalogued as rs751499392; called by muse, mutect2, varscan2
- RNF214 | c.401C>G p.S134C | Missense Mutation (SNP) | VAF 56/104 reads (54%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.847); catalogued as COSV56119653; called by muse, mutect2, varscan2
- RNF225 | c.406G>A p.D136N | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT tolerated (0.19); PolyPhen benign (0.32); catalogued as rs989671976; called by muse, mutect2, varscan2
- RNF8 | c.361G>C p.E121Q | Missense Mutation (SNP) | VAF 81/166 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV57722080; called by muse, mutect2, varscan2
- ROBO1 | c.2021G>A p.G674E | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs765149483; called by muse, varscan2
- ROCK1 | c.1220C>G p.S407C | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV67696085; called by muse, mutect2, varscan2
- ROPN1B | c.230C>G p.S77C | Missense Mutation (SNP) | VAF 29/52 reads (56%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs780039344, COSV99305680; called by muse, mutect2, varscan2
- RPL10L | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 63/133 reads (47%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.595); catalogued as rs750735739, COSV53560046; called by muse, mutect2, varscan2
- RPS27 | c.48G>C p.K16N | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.03); catalogued as COSV55143426; called by muse, mutect2
- RSRC1 | c.740C>G p.S247* | Nonsense Mutation (SNP) | VAF 20/40 reads (50%) | catalogued as COSV99905691; called by muse, mutect2, varscan2
- RSRC2 | c.296G>A p.R99K | Missense Mutation (SNP) | VAF 62/122 reads (51%) | SIFT tolerated, low confidence (0.25); PolyPhen possibly damaging (0.87); catalogued as COSV59204174; called by muse, mutect2, varscan2
- RTTN | c.3712C>T p.Q1238* | Nonsense Mutation (SNP) | VAF 26/46 reads (57%) | catalogued as COSV55342617; called by muse, mutect2, varscan2
- RTTN | c.851C>T p.S284F | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as COSV99731619; called by muse, mutect2, varscan2
- RYR1 | c.5074C>T p.Q1692* | Nonsense Mutation (SNP) | VAF 71/132 reads (54%) | catalogued as COSV62088524; called by muse, mutect2, varscan2
- RYR1 | c.8448G>A p.M2816I | Missense Mutation (SNP) | VAF 37/75 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV62102577; called by muse, mutect2, varscan2
- RYR3 | c.6820G>A p.E2274K (on ENST00000389232; = p.E2275K on NM_001036.6) | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.223); catalogued as rs978734656; called by muse, mutect2, varscan2
- SAMD9 | c.4351G>T p.E1451* | Nonsense Mutation (SNP) | VAF 127/224 reads (57%) | catalogued as COSV66078044; called by muse, mutect2, varscan2
- SBK2 | c.1003G>A p.E335K | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs553624707, COSV100705139, COSV60014020; called by muse, mutect2, varscan2
- SCAF1 | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 55/121 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.217); catalogued as COSV62183978; called by muse, mutect2, varscan2
- SCAP | c.2602G>A p.G868R | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated (0.55); PolyPhen benign (0.376); catalogued as rs749293673; called by muse, mutect2, varscan2
- SCARF1 | c.941G>A p.R314Q | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.033); catalogued as rs538940940, COSV53958038; called by muse, mutect2, varscan2
- SCN11A | c.2034C>G p.F678L | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs981721148, COSV56578469; called by muse, mutect2, varscan2
- SCN4B | c.617C>T p.S206L | Missense Mutation (SNP) | VAF 95/209 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs140348243, CM109585; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCNN1D | c.29G>A p.R10K (on ENST00000338555; = p.E143K on NM_001130413.4) | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); catalogued as rs1195921508; called by muse, mutect2, varscan2
- SCUBE2 | c.2059C>G p.P687A (on ENST00000649792 / NM_001367977.2; = p.P532A on NM_001170690.2) | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV58540321; called by muse, mutect2, varscan2
- SEC14L3 | c.460G>C p.D154H | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99307122; called by muse, mutect2, varscan2
- SEC16B | c.100C>T p.R34W | Missense Mutation (SNP) | VAF 66/148 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as rs969722881; called by muse, mutect2, varscan2
- SECISBP2L | c.694C>T p.L232F | Missense Mutation (SNP) | VAF 121/240 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.383); catalogued as rs1256755192; called by muse, mutect2, varscan2
- SELE | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 53/121 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.124); catalogued as rs1049175153; called by muse, mutect2, varscan2
- SELENOT | c.19C>T p.L7F | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as COSV72000400; called by muse, mutect2, varscan2
- SEMA5A | c.703G>C p.E235Q | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV66806494; called by muse, mutect2, varscan2
- SERPINA5 | c.365G>A p.R122K | Missense Mutation (SNP) | VAF 104/218 reads (48%) | SIFT tolerated (0.49); PolyPhen benign (0.042); catalogued as rs1162598388; called by muse, mutect2, varscan2
- SETD2 | c.4069C>T p.L1357F | Missense Mutation (SNP) | VAF 62/150 reads (41%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0); catalogued as COSV100339953; called by muse, mutect2, varscan2
- SETD2 | c.2650C>T p.Q884* | Nonsense Mutation (SNP) | VAF 59/119 reads (50%) | catalogued as COSV57431254; called by muse, mutect2, varscan2
- SF3B1 | c.2723C>T p.S908L | Missense Mutation (SNP) | VAF 61/98 reads (62%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV59223826; called by muse, mutect2, varscan2
- SF3B3 | c.2617C>T p.Q873* | Nonsense Mutation (SNP) | VAF 29/82 reads (35%) | catalogued as COSV100210167; called by muse, mutect2, varscan2
- SFXN3 | c.118C>G p.L40V | Missense Mutation (SNP) | VAF 69/152 reads (45%) | SIFT tolerated (0.93); PolyPhen benign (0.044); catalogued as rs1482879782; called by muse, mutect2, varscan2
- SH2B1 | c.575del p.P192Qfs*3 | Frame Shift Del (DEL) | VAF 47/120 reads (39%) | catalogued as COSV59464467; called by mutect2, pindel, varscan2
- SH3KBP1 | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 56/118 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65643856; called by muse, mutect2, varscan2
- SHF | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 77/166 reads (46%) | SIFT tolerated (0.84); PolyPhen benign (0.034); catalogued as rs773800910; called by muse, mutect2, varscan2
- SHISA7 | c.833G>A p.R278Q | Missense Mutation (SNP) | VAF 43/92 reads (47%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.953); catalogued as rs1021841055; called by muse, mutect2, varscan2
- SIGLEC5 | c.1160C>T p.S387L | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1261665139; called by muse, mutect2, varscan2
- SIGLEC6 | c.384G>A p.M128I | Missense Mutation (SNP) | VAF 59/121 reads (49%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV100585110; called by muse, mutect2, varscan2
- SIK3 | c.2003C>T p.S668L (on ENST00000445177 / NM_001366686.2; = p.S626L on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/86 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1454190473, COSV52619402; called by muse, mutect2, varscan2
- SIMC1 | c.1217C>T p.S406L (on ENST00000443967 / NM_001308196.1; = p.S425L on NM_001308195.2) | Missense Mutation (SNP) | VAF 20/159 reads (13%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.736); catalogued as rs571099671; called by muse, mutect2, varscan2
- SIPA1L1 | c.1697G>A p.R566K | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs754769583, COSV99059979; called by muse, mutect2, varscan2
- SIX5 | c.559C>T p.R187* | Nonsense Mutation (SNP) | VAF 50/98 reads (51%) | catalogued as COSV52178983; called by muse, mutect2, varscan2
- SLA2 | c.48G>T p.L16F | Missense Mutation (SNP) | VAF 93/183 reads (51%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs868760349; called by muse, mutect2, varscan2
- SLC14A2 | c.1428G>C p.R476S | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.025); catalogued as COSV99675020; called by muse, mutect2, varscan2
- SLC22A24 | c.1217G>A p.R406Q | Missense Mutation (SNP) | VAF 50/97 reads (52%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.538); catalogued as rs1047710524, COSV70300288; called by muse, mutect2, varscan2
- SLC22A24 | c.934G>A p.E312K | Missense Mutation (SNP) | VAF 192/377 reads (51%) | SIFT tolerated (0.19); PolyPhen benign (0.033); catalogued as rs1307221635; called by muse, mutect2, varscan2
- SLC22A9 | c.515G>A p.R172K | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1293601521; called by muse, mutect2, varscan2
- SLC25A21 | c.665C>G p.S222* | Nonsense Mutation (SNP) | VAF 78/189 reads (41%) | catalogued as COSV58728019; called by muse, mutect2, varscan2
- SLC25A32 | c.303C>G p.F101L | Missense Mutation (SNP) | VAF 66/157 reads (42%) | SIFT tolerated (0.6); PolyPhen benign (0.012); catalogued as COSV52568651; called by muse, mutect2, varscan2
- SLC26A8 | c.2725G>A p.E909K | Missense Mutation (SNP) | VAF 78/179 reads (44%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.013); catalogued as rs1197574150; called by muse, mutect2, varscan2
- SLC44A5 | c.2026G>C p.E676Q | Missense Mutation (SNP) | VAF 127/278 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.491); catalogued as rs529370554; called by muse, mutect2, varscan2
- SLC4A10 | c.3256G>C p.D1086H (on ENST00000446997 / NM_001354461.2; = p.D1056H on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 46/118 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV55790823; called by muse, mutect2, varscan2
- SLC5A1 | c.1428C>G p.F476L | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.4); catalogued as rs753632204; called by muse, mutect2, varscan2
- SLC6A7 | c.569G>A p.S190N | Missense Mutation (SNP) | VAF 49/101 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1241579842; called by muse, mutect2, varscan2
- SLC9A5 | c.1786G>A p.E596K | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs778053322; called by muse, mutect2, varscan2
- SLC9C1 | c.1879C>T p.P627S | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs867296641, COSV99998295; called by muse, mutect2, varscan2
- SLCO1C1 | c.388C>T p.Q130* | Nonsense Mutation (SNP) | VAF 9/283 reads (3%) | catalogued as COSV56877228; called by muse, mutect2
- SLCO4C1 | c.608C>T p.S203F | Missense Mutation (SNP) | VAF 45/113 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.222); catalogued as rs1469507116; called by muse, mutect2, varscan2
- SLFN11 | c.2501G>T p.R834M | Missense Mutation (SNP) | VAF 124/393 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.102); catalogued as rs1162497340; called by muse, mutect2, varscan2
- SLIT1 | c.3244G>A p.E1082K | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT tolerated (0.87); PolyPhen benign (0.001); catalogued as rs765166328; called by muse, mutect2, varscan2
- SMYD3 | c.1170G>A p.M390I (on ENST00000490107 / NM_001375962.1; = p.M331I on NM_022743.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 58/103 reads (56%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as rs899321147; called by muse, mutect2, varscan2
- SNED1 | c.3841G>A p.E1281K | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as rs373865004; called by muse, mutect2, varscan2
- SNX6 | c.547C>A p.Q183K (on ENST00000652385; = p.Q55K on NM_021249.5) | Missense Mutation (SNP) | VAF 35/69 reads (51%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.53); catalogued as COSV61917940; called by muse, mutect2, varscan2
- SOX8 | c.259C>T p.P87S | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.838); catalogued as rs865789951; called by muse, mutect2, varscan2
- SOX9 | c.791G>A p.R264K | Missense Mutation (SNP) | VAF 156/238 reads (66%) | SIFT tolerated (0.23); PolyPhen benign (0.056); catalogued as rs778047936, COSV55421835, COSV55423870; called by muse, mutect2, varscan2
- SP140 | c.457G>A p.D153N | Missense Mutation (SNP) | VAF 52/145 reads (36%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.76); catalogued as rs1220942397; called by muse, mutect2, varscan2
- SPARC | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 95/181 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.275); catalogued as rs1386424217, COSV50558114; called by muse, mutect2, varscan2
- SPAST | c.286G>A p.A96T | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as CD004679; called by muse, mutect2, varscan2
- SPATA31E1 | c.665C>T p.S222F | Missense Mutation (SNP) | VAF 169/355 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.698); catalogued as rs201798562; called by muse, mutect2, varscan2
- SPHKAP | c.1780G>C p.E594Q | Missense Mutation (SNP) | VAF 58/116 reads (50%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV100764259, COSV60878584; called by muse, mutect2, varscan2
- SPTBN5 | c.8119G>A p.E2707K | Missense Mutation (SNP) | VAF 52/114 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as rs1170200307; called by muse, mutect2
- SRCAP | c.5611C>T p.R1871W | Missense Mutation (SNP) | VAF 52/119 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV99349041; called by muse, mutect2, varscan2
- SRCIN1 | c.1949C>T p.S650L (on ENST00000621492; = p.S616L on NM_025248.3) | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs754502674; called by muse, mutect2
- SRRD | c.229G>A p.D77N | Missense Mutation (SNP) | VAF 41/82 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as COSV99314583; called by muse, mutect2, varscan2
- STAB1 | c.137C>T p.S46L | Missense Mutation (SNP) | VAF 71/142 reads (50%) | SIFT deleterious (0.05); PolyPhen benign (0.006); catalogued as rs371443828, COSV58742304; called by muse, mutect2, varscan2
- STAB2 | c.1949G>A p.G650E | Missense Mutation (SNP) | VAF 115/222 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV66341395, COSV66342469; called by muse, mutect2, varscan2
- STAT4 | c.1741G>C p.E581Q | Missense Mutation (SNP) | VAF 108/259 reads (42%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as COSV100635957; called by muse, mutect2, varscan2
- SULF1 | c.1838G>A p.R613Q | Missense Mutation (SNP) | VAF 50/101 reads (50%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.558); catalogued as rs776730164; called by muse, mutect2, varscan2
- SWT1 | c.2071C>G p.L691V | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.991); catalogued as COSV62253900; called by muse, mutect2, varscan2
- SYCP2 | c.3431C>T p.S1144L | Missense Mutation (SNP) | VAF 30/52 reads (58%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as rs1449621938; called by muse, mutect2, varscan2
- SYCP3 | c.379C>T p.Q127* | Nonsense Mutation (SNP) | VAF 14/39 reads (36%) | catalogued as COSV99901748; called by muse, mutect2, varscan2
- SYNE1 | c.24532G>A p.E8178K (on ENST00000367255 / NM_182961.4; = p.E8107K on NM_033071.3) | Missense Mutation (SNP) | VAF 60/112 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99571688; called by muse, mutect2, varscan2
- SYNE1 | c.24403G>A p.E8135K (on ENST00000367255 / NM_182961.4; = p.E8064K on NM_033071.3) | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55067724; called by muse, mutect2, varscan2
- SYTL2 | c.228G>A p.M76I | Missense Mutation (SNP) | VAF 19/180 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as rs937586863; called by muse, mutect2
- SYTL5 | c.1330G>A p.D444N | Missense Mutation (SNP) | VAF 25/149 reads (17%) | SIFT tolerated (0.46); PolyPhen benign (0.29); catalogued as COSV52903159; called by muse, mutect2, varscan2
- TACC1 | c.1951C>G p.Q651E | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs369036257; called by muse, mutect2, varscan2
- TACC2 | c.6458C>T p.T2153M (on ENST00000334433; = p.T231M on NM_006997.4) | Missense Mutation (SNP) | VAF 229/476 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs538567560, COSV53285519; called by muse, mutect2, varscan2
- TAF1 | c.2794G>A p.G932R (on ENST00000373790 / NM_138923.4; = p.G953R on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/65 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52107816, COSV99034758; called by muse, mutect2, varscan2
- TAOK3 | c.1354G>C p.E452Q | Missense Mutation (SNP) | VAF 157/353 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.342); catalogued as COSV66826619; called by muse, mutect2, varscan2
- TBC1D15 | c.1144G>C p.E382Q | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.106); catalogued as COSV100041462; called by muse, mutect2, varscan2
- TBC1D16 | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as rs1382684766, COSV60475790; called by muse, mutect2, varscan2
- TBC1D5 | c.584G>A p.R195K | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.694); catalogued as rs187828497; called by muse, mutect2, varscan2
- TBP | c.556C>T p.R186C | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs756227958, COSV57830402; called by muse, mutect2, varscan2
- TCF25 | c.2002G>A p.D668N | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs139621812; called by muse, mutect2, varscan2
- TCHHL1 | c.1408G>A p.E470K | Missense Mutation (SNP) | VAF 64/182 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV64287714; called by muse, mutect2, varscan2
- TCTE1 | c.412C>A p.R138S | Missense Mutation (SNP) | VAF 80/170 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.469); catalogued as COSV65255191; called by muse, mutect2, varscan2
- TDRD6 | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 48/102 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); catalogued as rs1167219279; called by muse, mutect2, varscan2
- TEAD2 | c.338G>C p.R113T | Missense Mutation (SNP) | VAF 41/87 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1462402927, COSV60874270; called by muse, mutect2, varscan2
- TECR | c.16-7C>T | Splice Region (SNP) | VAF 77/221 reads (35%) | catalogued as rs762614488, COSV53107990; called by muse, mutect2, varscan2
- TECR | c.563-3C>T | Splice Region (SNP) | VAF 92/391 reads (24%) | catalogued as rs982813732, COSV99294988; called by muse, mutect2, varscan2
4,772 further variants in this file (1,184 protein-altering or splice-affecting, 790 silent, 2,798 other) are not listed here.
